Somatic mutation profile of tumor specimen C3L-04365-02 (aliquot CPT0243560007) from CPTAC case C3L-04365, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA1; Tumor grade: G3; Age at diagnosis: 64.4 years (23,514 days).
Specimen C3L-04365-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 11b2485e-9add-47ec-8825-f908c1f99975.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-04365-31 (Blood Derived Normal), aliquot CPT0243710002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dbff2370-92d8-484d-af93-8888df05ffe2

The open-access MAF lists 905 somatic variants for this specimen: 603 protein-altering or splice-affecting, 194 silent, 108 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 528, Silent 194, Nonsense Mutation 52, Intron 45, RNA 23, 5'UTR 19, Splice Site 12, 3'Flank 8, 5'Flank 7, Splice Region 6, 3'UTR 6, Frame Shift Del 2.

Variants (750 of 905; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.811G>T p.E271* | Nonsense Mutation (SNP) | VAF 60/629 reads (10%) | hotspot (GDC flag); catalogued as COSV52666332, COSV52700326, COSV52746468; called by muse, mutect2
- TRPV4 | c.710G>T p.R237L | Missense Mutation (SNP) | VAF 20/434 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as rs1289139464, CM160667, COSV55682158; ClinVar: likely pathogenic; called by muse, mutect2
- ACADVL | c.1360G>C p.D454H | Missense Mutation (SNP) | VAF 31/579 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM990099; called by muse, mutect2
- ACSM2B | c.1325G>A p.W442* | Nonsense Mutation (SNP) | VAF 24/348 reads (7%) | catalogued as COSV61657582; called by muse, mutect2
- ACTB | c.373G>C p.E125Q | Missense Mutation (SNP) | VAF 18/412 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.103); catalogued as COSV59319301; called by muse, mutect2
- ADAM11 | c.1412G>A p.G471D | Missense Mutation (SNP) | VAF 15/259 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as COSV52347364; called by muse, mutect2
- ADAMTS18 | c.2471C>G p.S824C | Missense Mutation (SNP) | VAF 30/492 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV51418461; called by muse, mutect2
- ADCY6 | c.1861G>A p.E621K | Missense Mutation (SNP) | VAF 21/256 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100326860; called by muse, mutect2
- ADCY8 | c.2606A>G p.Y869C | Missense Mutation (SNP) | VAF 14/318 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1372422555, COSV53915844; called by muse, mutect2
- ADCY8 | c.1421C>A p.P474H | Missense Mutation (SNP) | VAF 25/289 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1480654902, COSV53923031; called by muse, mutect2
- AKAP6 | c.6343C>G p.L2115V | Missense Mutation (SNP) | VAF 11/236 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55228809; called by muse, mutect2
- ANK2 | c.8440C>T p.L2814F | Missense Mutation (SNP) | VAF 32/433 reads (7%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.136); catalogued as COSV52150017; called by muse, mutect2
- ANKRD36 | c.4835G>A p.R1612Q | Missense Mutation (SNP) | VAF 22/710 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.409); catalogued as rs942230541, COSV100825877; called by muse, mutect2
- APC2 | c.4807G>A p.E1603K | Missense Mutation (SNP) | VAF 19/264 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs1211925931; called by muse, mutect2
- APP | c.1834G>A p.E612K | Missense Mutation (SNP) | VAF 20/477 reads (4%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.784); catalogued as COSV100696381; called by muse, mutect2
- ARFGEF2 | c.2532G>C p.Q844H | Missense Mutation (SNP) | VAF 9/138 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV64210412; called by muse, mutect2
- ARFGEF2 | c.4316-1G>T p.X1439_splice | Splice Site (SNP) | VAF 20/422 reads (5%) | catalogued as COSV64214549; called by muse, mutect2
- ARFGEF2 | c.4489G>C p.D1497H | Missense Mutation (SNP) | VAF 19/500 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.212); catalogued as COSV64210645; called by muse, mutect2
- ARHGAP30 | c.310C>G p.P104A | Missense Mutation (SNP) | VAF 11/208 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63516551; called by muse, mutect2
- ARHGAP31 | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 36/440 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs560059864; called by muse, mutect2
- ARID2 | c.3470C>G p.S1157* | Nonsense Mutation (SNP) | VAF 28/212 reads (13%) | catalogued as COSV100536615, COSV57603040; called by muse, mutect2, varscan2
- ARMC5 | c.859G>T p.V287F | Missense Mutation (SNP) | VAF 28/180 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.961); catalogued as COSV51655846; called by muse, mutect2, varscan2
- ASCC3 | c.271G>C p.E91Q | Missense Mutation (SNP) | VAF 19/248 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.416); catalogued as COSV100225682; called by muse, mutect2
- ASIC2 | c.1243G>C p.E415Q | Missense Mutation (SNP) | VAF 8/159 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56767597; called by muse, mutect2
- ATN1 | c.3322C>G p.L1108V | Missense Mutation (SNP) | VAF 14/322 reads (4%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.867); catalogued as COSV57547471; called by muse, mutect2
- ATXN1 | c.979G>A p.E327K | Missense Mutation (SNP) | VAF 16/288 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV55214430; called by muse, mutect2
- BIN1 | c.287G>C p.G96A | Missense Mutation (SNP) | VAF 42/630 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV99387952; called by muse, mutect2
- BOD1L2 | c.421C>T p.H141Y | Missense Mutation (SNP) | VAF 15/193 reads (8%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.796); catalogued as COSV73996864; called by muse, mutect2
- BPTF | c.2533G>C p.E845Q | Missense Mutation (SNP) | VAF 30/366 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100075160; called by muse, mutect2
- BROX | c.328G>C p.E110Q | Missense Mutation (SNP) | VAF 15/265 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV61799714; called by muse, mutect2
- C2orf16 | c.1340C>T p.S447L | Missense Mutation (SNP) | VAF 16/201 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.541); catalogued as COSV101284385, COSV68647212; called by muse, mutect2
- CACNB2 | c.1369C>G p.L457V (on ENST00000324631 / NM_201596.3; = p.L402V on NM_000724.4) | Missense Mutation (SNP) | VAF 26/502 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.523); catalogued as COSV56653852, COSV99030389; called by muse, mutect2
- CAPN2 | c.1421G>T p.R474L | Missense Mutation (SNP) | VAF 57/572 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs776355445, COSV54334212; called by muse, mutect2
- CBX8 | c.873C>G p.F291L | Missense Mutation (SNP) | VAF 17/419 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV53937231; called by muse, mutect2
- CCNF | c.690G>C p.R230S | Missense Mutation (SNP) | VAF 10/214 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as COSV53544081, COSV99563899; called by muse, mutect2
- CD200 | c.449C>A p.T150N (on ENST00000473539 / NM_001004196.3; = p.T125N on NM_005944.7 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/196 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs1256811153; called by muse, mutect2
- CDH20 | c.11C>G p.S4C | Missense Mutation (SNP) | VAF 11/172 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.431); catalogued as COSV53010984; called by muse, mutect2
- CELF5 | c.641C>G p.T214R | Missense Mutation (SNP) | VAF 12/266 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as rs1257950653, COSV53013947; called by muse, mutect2
- CELSR1 | c.632C>T p.S211L | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as rs1340328444; called by muse, mutect2
- CENPJ | c.2311G>C p.E771Q | Missense Mutation (SNP) | VAF 33/540 reads (6%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.782); catalogued as COSV101121474; called by muse, mutect2
- CHAF1A | c.514C>G p.P172A | Missense Mutation (SNP) | VAF 28/492 reads (6%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.013); catalogued as COSV56673497; called by muse, mutect2
- CIAO1 | c.116G>T p.R39I | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.025); catalogued as rs1364116631; called by muse, mutect2
- CIAO1 | c.172G>C p.E58Q | Missense Mutation (SNP) | VAF 23/163 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.16); catalogued as COSV51498265; called by muse, mutect2, varscan2
- CNTD1 | c.154G>T p.E52* | Nonsense Mutation (SNP) | VAF 10/166 reads (6%) | catalogued as COSV55910572; called by muse, mutect2
- COL20A1 | c.3675G>T p.E1225D | Missense Mutation (SNP) | VAF 28/233 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.212); catalogued as COSV100491094; called by muse, mutect2, varscan2
- COL21A1 | c.123C>G p.I41M | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55180310; called by muse, mutect2
- COL4A3 | c.3614G>C p.R1205T | Missense Mutation (SNP) | VAF 27/356 reads (8%) | SIFT tolerated (0.61); PolyPhen benign (0.233); catalogued as rs747299532; called by muse, mutect2
- COL6A3 | c.4799G>C p.R1600T | Missense Mutation (SNP) | VAF 13/214 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as COSV55099545; called by muse, mutect2
- COL9A1 | c.682C>G p.Q228E | Missense Mutation (SNP) | VAF 16/474 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV61827884, COSV61837684; called by muse, mutect2
- COMMD9 | c.566G>A p.R189Q | Missense Mutation (SNP) | VAF 21/237 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs1313643110; called by muse, mutect2
- COMP | c.1531G>A p.D511N | Missense Mutation (SNP) | VAF 24/555 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM043992, CM980438, COSV99721644; called by muse, mutect2
- CPD | c.2021C>T p.S674F | Missense Mutation (SNP) | VAF 14/312 reads (4%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.968); catalogued as COSV56717185; called by muse, mutect2
- CRTC2 | c.1924G>C p.E642Q | Missense Mutation (SNP) | VAF 29/707 reads (4%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as COSV57841796; called by muse, mutect2
- CTDP1 | c.2883G>C p.M961I | Missense Mutation (SNP) | VAF 22/404 reads (5%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.063); catalogued as COSV50009360; called by muse, mutect2
- CYLC2 | c.839C>A p.T280K | Missense Mutation (SNP) | VAF 11/153 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.013); catalogued as COSV66339982; called by muse, mutect2
- CYP17A1 | c.1022C>T p.T341I | Missense Mutation (SNP) | VAF 28/455 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.053); catalogued as rs1301250258; called by muse, mutect2
- DCAF1 | c.472C>G p.Q158E | Missense Mutation (SNP) | VAF 12/211 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as rs782025973; called by muse, mutect2
- DDC | c.1355C>T p.S452F | Missense Mutation (SNP) | VAF 32/616 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.975); catalogued as COSV63566416; called by muse, mutect2
- DNAH3 | c.3597G>C p.L1199F | Missense Mutation (SNP) | VAF 12/190 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54547660; called by muse, mutect2
- DOCK1 | c.77A>T p.D26V | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated (0.62); PolyPhen benign (0.006); catalogued as COSV54746670; called by muse, mutect2
- DPPA2 | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 22/250 reads (9%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs755881099, COSV72118291; called by muse, mutect2
- DSCAML1 | c.3436C>G p.L1146V (on ENST00000321322; = p.L1086V on NM_020693.4) | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100354486; called by muse, mutect2
- DSG2 | c.944G>C p.G315A | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV99852654; called by muse, mutect2
- E2F1 | c.392C>T p.S131L | Missense Mutation (SNP) | VAF 36/442 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58534737, COSV58536072; called by muse, mutect2
- EP400 | c.3301G>T p.E1101* | Nonsense Mutation (SNP) | VAF 30/348 reads (9%) | catalogued as COSV57780225; called by muse, mutect2
- ERBB3 | c.707C>T p.S236L | Missense Mutation (SNP) | VAF 29/513 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.094); catalogued as COSV57264899; called by muse, mutect2
- ERICH3 | c.2802G>T p.E934D | Missense Mutation (SNP) | VAF 22/203 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.046); catalogued as COSV58607350; called by muse, mutect2, varscan2
- ERLIN2 | c.85G>T p.G29* | Nonsense Mutation (SNP) | VAF 38/716 reads (5%) | catalogued as COSV99379492; called by muse, mutect2
- EVPL | c.4746G>C p.Q1582H | Missense Mutation (SNP) | VAF 22/298 reads (7%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.747); catalogued as COSV101440981; called by muse, mutect2
- EWSR1 | c.1669C>G p.P557A | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.332); catalogued as COSV100132190; called by muse, mutect2
- EYA1 | c.1640G>C p.R547T | Missense Mutation (SNP) | VAF 12/260 reads (5%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.981); catalogued as COSV100378606; called by muse, mutect2
- F2RL2 | c.148G>C p.E50Q | Missense Mutation (SNP) | VAF 24/330 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0.051); catalogued as COSV56971385; called by muse, mutect2
- FAM53C | c.326C>A p.P109H | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.627); catalogued as COSV53513132; called by muse, mutect2
- FARSB | c.119C>G p.S40C | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV56050159; called by muse, mutect2
- FGG | c.487G>C p.E163Q | Missense Mutation (SNP) | VAF 17/473 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.257); catalogued as COSV100271664; called by muse, mutect2
- FHOD3 | c.602C>G p.S201* | Nonsense Mutation (SNP) | VAF 8/136 reads (6%) | catalogued as rs1437521682, COSV57192895; called by muse, mutect2
- FLG2 | c.4487G>A p.R1496K | Missense Mutation (SNP) | VAF 44/512 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.506); catalogued as COSV66168383, COSV66170218; called by muse, mutect2
- FLNC | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 15/211 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV57963880; called by muse, mutect2
- FLT1 | c.601G>C p.E201Q | Missense Mutation (SNP) | VAF 26/311 reads (8%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.745); catalogued as COSV56729629; called by muse, mutect2
- FOCAD | c.2573T>C p.M858T | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs867858456; called by muse, mutect2, varscan2
- FRMPD1 | c.1792C>T p.R598C | Missense Mutation (SNP) | VAF 32/308 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs757647210; called by muse, mutect2, varscan2
- FSHR | c.1906G>C p.D636H | Missense Mutation (SNP) | VAF 28/571 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58622530; called by muse, mutect2
- FYB2 | c.231G>C p.Q77H | Missense Mutation (SNP) | VAF 13/215 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV100599242; called by muse, mutect2
- GIGYF2 | c.1337C>T p.S446F | Missense Mutation (SNP) | VAF 24/298 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.083); catalogued as COSV65248879; called by muse, mutect2
- GMPR2 | c.976G>C p.E326Q (on ENST00000355299 / NM_001351022.2; = p.E344Q on NM_016576.5) | Missense Mutation (SNP) | VAF 10/238 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV57468341; called by muse, mutect2
- GPATCH8 | c.1032G>C p.Q344H | Missense Mutation (SNP) | VAF 24/378 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.747); catalogued as rs1280107973, COSV59194293; called by muse, mutect2
- GPR157 | c.335C>T p.A112V | Missense Mutation (SNP) | VAF 14/210 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs1352594815, COSV66233227; called by muse, mutect2
- GPR162 | c.1192C>T p.L398F (on ENST00000311268 / NM_019858.2; = p.L114F on NM_014449.2) | Missense Mutation (SNP) | VAF 22/190 reads (12%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.047); catalogued as COSV99301698; called by muse, mutect2, varscan2
- GRIN2A | c.3005C>G p.T1002R | Missense Mutation (SNP) | VAF 32/465 reads (7%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.53); catalogued as rs749997301; called by muse, mutect2
- HECTD4 | c.9744C>G p.F3248L | Missense Mutation (SNP) | VAF 13/231 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV66401921; called by muse, mutect2
- HELZ2 | c.5161C>G p.Q1721E (on ENST00000467148 / NM_001037335.2; = p.Q1152E on NM_033405.3) | Missense Mutation (SNP) | VAF 13/332 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1331483263, COSV101427524, COSV71295381; called by muse, mutect2
- HFM1 | c.3563C>G p.S1188C | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.035); catalogued as rs1303059584, COSV54021164; called by muse, mutect2, varscan2
- HGF | c.368-1G>C p.X123_splice | Splice Site (SNP) | VAF 14/286 reads (5%) | catalogued as COSV55948930, COSV55955638; called by muse, mutect2
- HOXC9 | c.200C>A p.A67E | Missense Mutation (SNP) | VAF 20/410 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.33); catalogued as COSV57716800; called by muse, mutect2
- HTR1F | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 13/178 reads (7%) | SIFT tolerated (0.43); PolyPhen benign (0.229); catalogued as COSV60390863; called by muse, mutect2
- HYAL2 | c.1351G>A p.E451K | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT tolerated (0.91); PolyPhen benign (0.001); catalogued as rs373307469, COSV63305883; called by muse, mutect2
- IFI44L | c.479-4A>G | Splice Region (SNP) | VAF 17/132 reads (13%) | catalogued as rs1474900334; called by muse, mutect2, varscan2
- IGLV6-57 | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 32/338 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.343); catalogued as rs761458652; called by muse, mutect2
- INTS3 | c.2318A>T p.Q773L | Missense Mutation (SNP) | VAF 12/194 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV55162825; called by muse, mutect2
- IPO5 | c.698A>G p.D233G | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs1398696257, COSV55159020; called by muse, mutect2, varscan2
- ISLR2 | c.1489G>A p.E497K | Missense Mutation (SNP) | VAF 31/196 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.153); catalogued as rs1304784130, COSV62304266; called by muse, mutect2, varscan2
- JPH1 | c.438C>G p.S146R | Missense Mutation (SNP) | VAF 26/278 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV60611320; called by muse, mutect2
- KIFAP3 | c.2191G>C p.E731Q | Missense Mutation (SNP) | VAF 12/275 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV100846735; called by muse, mutect2
- KLC2 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 14/356 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.075); catalogued as rs1240569511, COSV100385267, COSV57582504, COSV57583573; called by muse, mutect2
- KMT2B | c.5248G>C p.E1750Q | Missense Mutation (SNP) | VAF 22/498 reads (4%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.974); catalogued as COSV55865522; called by muse, mutect2
- KRTAP4-6 | c.79C>G p.Q27E | Missense Mutation (SNP) | VAF 22/466 reads (5%) | SIFT tolerated (0.07); catalogued as rs1324670225, COSV100624143; called by muse, mutect2
- LCE2A | c.305C>G p.S102C | Missense Mutation (SNP) | VAF 23/165 reads (14%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.996); catalogued as COSV64226838; called by muse, mutect2
- LIM2 | c.512C>T p.T171I (on ENST00000596399 / NM_001161748.2; = p.T213I on NM_030657.4) | Missense Mutation (SNP) | VAF 40/448 reads (9%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.02); catalogued as rs770813550; called by muse, mutect2
- LRRIQ1 | c.3693G>C p.Q1231H | Missense Mutation (SNP) | VAF 30/534 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as COSV67825729, COSV67827630; called by muse, mutect2
- LYG1 | c.570G>C p.K190N | Missense Mutation (SNP) | VAF 11/264 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.42); catalogued as COSV57915993; called by muse, mutect2
- MAGEE1 | c.1639G>C p.E547Q | Missense Mutation (SNP) | VAF 10/117 reads (9%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.996); catalogued as rs782360301, COSV100819544; called by muse, mutect2
- MAP3K1 | c.3149G>C p.R1050T | Missense Mutation (SNP) | VAF 14/175 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as rs1273847896; called by muse, mutect2
- MAP7 | c.1869G>C p.Q623H | Missense Mutation (SNP) | VAF 11/255 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs934538605; called by muse, mutect2
- MECOM | c.1315C>T p.Q439* (on ENST00000468789 / NM_001105078.4; = p.Q627* on NM_004991.4) | Nonsense Mutation (SNP) | VAF 24/320 reads (8%) | catalogued as COSV52962995; called by muse, mutect2
- MME | c.354G>C p.L118F | Missense Mutation (SNP) | VAF 15/272 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV64707502; called by muse, mutect2
- MRC1 | c.32C>T p.S11F | Missense Mutation (SNP) | VAF 42/706 reads (6%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs1445835500; called by muse, mutect2
- MYH1 | c.3389G>A p.R1130Q | Missense Mutation (SNP) | VAF 63/474 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.982); catalogued as rs199524427, COSV56848254; called by muse, mutect2, varscan2
- MYH11 | c.5863G>C p.E1955Q | Missense Mutation (SNP) | VAF 16/392 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.04); catalogued as COSV55564260; called by muse, mutect2
- NANS | c.758C>T p.S253L | Missense Mutation (SNP) | VAF 13/304 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1483044560; called by muse, mutect2
- NBEAL2 | c.4088C>G p.S1363C | Missense Mutation (SNP) | VAF 26/496 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.159); catalogued as rs1255872281; called by muse, mutect2
- NCAM1 | c.1657G>C p.E553Q (on ENST00000316851 / NM_181351.5; = p.E543Q on NM_000615.7) | Missense Mutation (SNP) | VAF 12/202 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV57527197; called by muse, mutect2
- NCOR1 | c.6860C>G p.S2287C | Missense Mutation (SNP) | VAF 24/405 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.241); catalogued as COSV51968477; called by muse, mutect2
- NFRKB | c.151G>C p.D51H (on ENST00000446488 / NM_001143835.2; = p.D64H on NM_006165.3) | Missense Mutation (SNP) | VAF 9/216 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.365); catalogued as COSV100452056; called by muse, mutect2
- NLRC5 | c.250C>G p.L84V | Missense Mutation (SNP) | VAF 28/185 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); catalogued as COSV52649834; called by muse, mutect2
- NLRP13 | c.406G>A p.G136R | Missense Mutation (SNP) | VAF 19/243 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1211364363, COSV100738113; called by muse, mutect2
- NPPA | c.220C>G p.L74V | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as rs1486885368, COSV56737743; called by muse, mutect2
- NPTX1 | c.338C>G p.S113W | Missense Mutation (SNP) | VAF 48/536 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.68); catalogued as COSV60776074; called by muse, mutect2
- NUP133 | c.641C>G p.A214G | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.914); catalogued as COSV54569858; called by muse, mutect2
- NUP62 | c.144C>G p.F48L | Missense Mutation (SNP) | VAF 47/716 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV61311413, COSV61313504; called by muse, mutect2
- NXT1 | c.158C>G p.S53* | Nonsense Mutation (SNP) | VAF 22/466 reads (5%) | catalogued as COSV54782995; called by muse, mutect2
- OGDHL | c.1633G>C p.E545Q | Missense Mutation (SNP) | VAF 15/223 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.248); catalogued as COSV104427168, COSV65103355; called by muse, mutect2
- OLFML2B | c.727G>C p.E243Q | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.207); catalogued as COSV54198068; called by muse, mutect2
- OR2B3 | c.469G>C p.V157L | Missense Mutation (SNP) | VAF 16/308 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.057); catalogued as COSV65851122; called by muse, mutect2
- OR51A4 | c.142C>G p.L48V | Missense Mutation (SNP) | VAF 19/427 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV100985356; called by muse, mutect2
- OR51I2 | c.607C>T p.L203F | Missense Mutation (SNP) | VAF 20/372 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58297833; called by muse, mutect2
- OR56B1 | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 47/432 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.394); catalogued as rs767967322, COSV100402622; called by muse, mutect2, varscan2
- OTOGL | c.2094C>A p.Y698* (on ENST00000547103; = p.Y689* on NM_173591.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 19/429 reads (4%) | catalogued as COSV101509388; called by muse, mutect2
- PADI1 | c.1585G>C p.E529Q | Missense Mutation (SNP) | VAF 12/298 reads (4%) | SIFT tolerated (0.96); PolyPhen benign (0.031); catalogued as COSV64938472; called by muse, mutect2
- PAK1 | c.748G>T p.D250Y | Missense Mutation (SNP) | VAF 12/190 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV53703512; called by muse, mutect2
- PARD3 | c.676C>T p.H226Y | Missense Mutation (SNP) | VAF 12/247 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as rs1353694076; called by muse, mutect2
- PARP1 | c.649G>C p.D217H | Missense Mutation (SNP) | VAF 16/350 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.546); catalogued as COSV64688092; called by muse, mutect2
- PCDHA13 | c.67G>T p.A23S | Missense Mutation (SNP) | VAF 15/288 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.014); catalogued as COSV56514798; called by muse, mutect2
- PCID2 | c.1110G>T p.M370I | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as COSV55813178; called by muse, mutect2
- PCLO | c.4601G>A p.G1534D | Missense Mutation (SNP) | VAF 19/151 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.77); catalogued as rs1346415937; called by muse, mutect2, varscan2
- PDZD8 | c.618C>G p.I206M | Missense Mutation (SNP) | VAF 22/480 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57826234; called by muse, mutect2
- PER1 | c.3592G>C p.D1198H | Missense Mutation (SNP) | VAF 10/220 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV57920621; called by muse, mutect2
- PIP5K1A | c.454G>C p.E152Q (on ENST00000368888 / NM_001135638.2; = p.E139Q on NM_003557.3) | Missense Mutation (SNP) | VAF 27/398 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as COSV62959430; called by muse, mutect2
- PLAAT5 | c.556G>C p.E186Q | Missense Mutation (SNP) | VAF 27/468 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.091); catalogued as COSV100080397; called by muse, mutect2
- PLEC | c.12549G>T p.Q4183H (on ENST00000322810 / NM_201380.4; = p.Q4073H on NM_000445.5) | Missense Mutation (SNP) | VAF 26/466 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV100519998; called by muse, mutect2
- PLXNB2 | c.3273C>A p.Y1091* | Nonsense Mutation (SNP) | VAF 39/401 reads (10%) | catalogued as COSV63781612; called by muse, mutect2, varscan2
- POM121L12 | c.577G>A p.D193N | Missense Mutation (SNP) | VAF 15/382 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.585); catalogued as rs1176072052, COSV68693559; called by muse, mutect2
- PRKAG3 | c.602C>G p.S201C | Missense Mutation (SNP) | VAF 20/282 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.034); catalogued as rs948666411, COSV52102130; called by muse, mutect2
- PRR5L | c.692C>G p.S231* | Nonsense Mutation (SNP) | VAF 11/211 reads (5%) | catalogued as COSV100287367; called by muse, mutect2
- PTEN | c.59G>C p.G20A | Missense Mutation (SNP) | VAF 24/472 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.249); catalogued as COSV64288474, COSV64294113, COSV64299088; called by muse, mutect2
- RAB5A | c.584G>C p.R195T | Missense Mutation (SNP) | VAF 12/286 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1285345308; called by muse, mutect2
- RALGAPA2 | c.1292G>A p.R431K | Missense Mutation (SNP) | VAF 18/187 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0.209); catalogued as COSV52503646; called by muse, mutect2, varscan2
- RGPD4 | c.3904C>A p.P1302T | Missense Mutation (SNP) | VAF 78/954 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.647); catalogued as rs761919430; called by muse, mutect2
- RNF146 | c.676G>A p.D226N (on ENST00000368314 / NM_001242850.2; = p.D225N on NM_030963.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/362 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.052); catalogued as rs1164525127, COSV58934810; called by muse, mutect2, varscan2
- RNGTT | c.212C>G p.S71* | Nonsense Mutation (SNP) | VAF 11/198 reads (6%) | catalogued as COSV55646238; called by muse, mutect2
- SACS | c.1054C>G p.L352V | Missense Mutation (SNP) | VAF 22/230 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.246); catalogued as COSV66544421; called by muse, mutect2
- SALL1 | c.341C>G p.S114* | Nonsense Mutation (SNP) | VAF 32/700 reads (5%) | catalogued as COSV51763925; called by muse, mutect2
- SALL3 | c.3560G>A p.G1187D | Missense Mutation (SNP) | VAF 22/286 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV73305791; called by muse, mutect2
- SATB1 | c.1602G>C p.W534C | Missense Mutation (SNP) | VAF 13/273 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58671784; called by muse, mutect2
- SECISBP2 | c.106G>T p.E36* | Nonsense Mutation (SNP) | VAF 19/474 reads (4%) | catalogued as COSV104405134; called by muse, mutect2
- SEMA6D | c.1960G>C p.E654Q (on ENST00000316364 / NM_153618.2; = p.E592Q on NM_020858.2) | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.147); catalogued as COSV60373498; called by muse, mutect2
- SLC8A3 | c.469G>T p.G157C | Missense Mutation (SNP) | VAF 15/295 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63525076; called by muse, mutect2
- SMAD3 | c.1247C>A p.S416Y | Missense Mutation (SNP) | VAF 30/332 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV59286689; called by muse, mutect2
- SOCS3 | c.273G>C p.K91N | Missense Mutation (SNP) | VAF 18/442 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV58270748; called by muse, mutect2
- SP3 | c.607C>G p.Q203E | Missense Mutation (SNP) | VAF 32/420 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.201); catalogued as rs1267404196; called by muse, mutect2
- SP9 | c.16C>T p.L6F | Missense Mutation (SNP) | VAF 14/230 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs1341440095; called by muse, mutect2
- STAT5A | c.2113G>C p.E705Q | Missense Mutation (SNP) | VAF 17/394 reads (4%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.78); catalogued as COSV52891363; called by muse, mutect2
- STK40 | c.699G>C p.Q233H | Missense Mutation (SNP) | VAF 33/472 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV63734853; called by muse, mutect2
- STXBP5L | c.1690G>C p.E564Q | Missense Mutation (SNP) | VAF 7/130 reads (5%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.767); catalogued as COSV56534504; called by muse, mutect2
- SYT6 | c.443C>G p.S148W (on ENST00000610222 / NM_001366225.1; = p.S63W on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/424 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV65772675; called by muse, mutect2
- TAS2R13 | c.24C>G p.I8M | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs530699969; called by muse, mutect2
- TASOR | c.223C>G p.Q75E | Missense Mutation (SNP) | VAF 12/272 reads (4%) | SIFT tolerated (0.39); PolyPhen benign (0.059); catalogued as rs1325943531; called by muse, mutect2
- TATDN2 | c.349C>G p.L117V | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs765089984; called by muse, mutect2, varscan2
- TBL1X | c.295G>A p.A99T | Missense Mutation (SNP) | VAF 17/228 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1316246048; called by muse, mutect2
- TEAD1 | c.1131G>C p.M377I | Missense Mutation (SNP) | VAF 14/291 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); catalogued as COSV100533067; called by muse, mutect2
- TENM2 | c.3034G>A p.E1012K (on ENST00000518659 / NM_001122679.2; = p.E780K on NM_001080428.3) | Missense Mutation (SNP) | VAF 16/355 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1368396537; called by muse, mutect2
- TET2 | c.3616G>T p.E1206* | Nonsense Mutation (SNP) | VAF 13/334 reads (4%) | catalogued as COSV54418149; called by muse, mutect2
- TEX2 | c.2926G>A p.E976K (on ENST00000583097 / NM_001288733.2; = p.E983K on NM_018469.5) | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV51985662; called by muse, mutect2
- TFAP2B | c.1223C>T p.P408L | Missense Mutation (SNP) | VAF 72/533 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777844146, COSV99540528; called by muse, mutect2, varscan2
- THBS2 | c.260C>T p.T87M | Missense Mutation (SNP) | VAF 19/170 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs757929890, COSV64678717, COSV64678851; called by muse, mutect2, varscan2
- THG1L | c.757G>C p.E253Q | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.031); catalogued as COSV99180224; called by muse, mutect2
- TMTC4 | c.1317G>A p.K439= (on ENST00000376234 / NM_001350577.2; = p.K458= on NM_032813.5 and 2 other RefSeq transcripts) | Splice Region (SNP) | VAF 10/82 reads (12%) | catalogued as rs1288700759; called by muse, mutect2, varscan2
- TPX2 | c.374del p.S125Lfs*14 | Frame Shift Del (DEL) | VAF 8/84 reads (10%) | catalogued as COSV55917411; called by mutect2, pindel
- TRAF2 | c.682G>C p.E228Q | Missense Mutation (SNP) | VAF 8/137 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV99916092; called by muse, mutect2
- TRPC6 | c.478C>G p.R160G | Missense Mutation (SNP) | VAF 40/424 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60259652; called by muse, mutect2
- TSHZ3 | c.772C>T p.R258C | Missense Mutation (SNP) | VAF 9/122 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53678114, COSV53679014; called by muse, mutect2
- TTN | c.43492G>A p.E14498K (on ENST00000591111; = p.E7074K on NM_003319.4) | Missense Mutation (SNP) | VAF 28/308 reads (9%) | PolyPhen probably damaging (0.994); catalogued as COSV60138911, COSV60333810; called by muse, mutect2
- UBN2 | c.2798C>G p.S933* | Nonsense Mutation (SNP) | VAF 15/274 reads (5%) | catalogued as COSV56029214; called by muse, mutect2
- UGT8 | c.1096G>C p.E366Q | Missense Mutation (SNP) | VAF 23/293 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60417031; called by muse, mutect2
- UNC79 | c.2605C>G p.Q869E (on ENST00000393151 / NM_001346218.2; = p.Q692E on NM_020818.5) | Missense Mutation (SNP) | VAF 12/204 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV56392641, COSV56402670; called by muse, mutect2
- USP46 | c.1083C>G p.F361L | Missense Mutation (SNP) | VAF 16/282 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as COSV71513187; called by muse, mutect2
- VEZT | c.836A>G p.Y279C | Missense Mutation (SNP) | VAF 14/276 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.947); catalogued as rs1315560412; called by muse, mutect2
- VPS28 | c.473G>A p.R158Q | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.067); catalogued as rs151274166, COSV52871770; called by muse, mutect2, varscan2
- WNK1 | c.2935C>A p.P979T | Missense Mutation (SNP) | VAF 18/416 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.381); catalogued as COSV60028218; called by muse, mutect2
- ZFP36L2 | c.626G>T p.G209V | Missense Mutation (SNP) | VAF 80/881 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV56700461, COSV99143504; called by muse, mutect2
- ZHX2 | c.611A>T p.E204V | Missense Mutation (SNP) | VAF 34/424 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.328); catalogued as COSV58711058; called by muse, mutect2
- ZNF14 | c.1452C>A p.F484L | Missense Mutation (SNP) | VAF 16/258 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100694113; called by muse, mutect2
- ZNF512B | c.1876G>A p.D626N | Missense Mutation (SNP) | VAF 11/234 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.285); catalogued as COSV53873671; called by muse, mutect2
- ZNF608 | c.3120G>C p.K1040N | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.109); catalogued as COSV60435487; called by muse, mutect2
- ZNF624 | c.2077G>C p.E693Q | Missense Mutation (SNP) | VAF 10/222 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60939189; called by muse, mutect2
- ZNF664 | c.172G>C p.V58L | Missense Mutation (SNP) | VAF 17/458 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV61878219; called by muse, mutect2
- ZNF726 | c.635G>T p.W212L | Missense Mutation (SNP) | VAF 14/204 reads (7%) | SIFT tolerated (0.64); PolyPhen benign (0.376); catalogued as rs967402284; called by muse, mutect2
- A2M | c.133G>C p.E45Q | Missense Mutation (SNP) | VAF 16/298 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.323); called by muse, mutect2
- AATF | c.674G>C p.R225T | Missense Mutation (SNP) | VAF 7/128 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.05); called by muse, mutect2
- ABAT | c.35G>T p.C12F | Missense Mutation (SNP) | VAF 24/609 reads (4%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); called by muse, mutect2
- ABCA12 | c.4517C>G p.S1506C (on ENST00000272895 / NM_173076.3; = p.S1188C on NM_015657.3) | Missense Mutation (SNP) | VAF 20/303 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- ABCA4 | c.4083G>C p.K1361N | Missense Mutation (SNP) | VAF 24/598 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2
- ABCC2 | c.2830G>C p.E944Q | Missense Mutation (SNP) | VAF 26/421 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.215); called by muse, mutect2
- ABI2 | c.1423G>C p.G475R (on ENST00000295851 / NM_001375719.1; = p.G437R on NM_005759.7 and 35 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- AC004922.1 | c.1903C>G p.Q635E | Missense Mutation (SNP) | VAF 20/355 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.499); called by muse, mutect2
- ADAM22 | c.2200G>T p.G734C | Missense Mutation (SNP) | VAF 22/198 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by mutect2, varscan2
- ADCY8 | c.1420C>A p.P474T | Missense Mutation (SNP) | VAF 25/292 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, mutect2
- ADGRG3 | c.1642C>G p.Q548E | Missense Mutation (SNP) | VAF 14/287 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.039); called by muse, mutect2
- ADRA1A | c.579C>G p.F193L | Missense Mutation (SNP) | VAF 30/460 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2
- AGAP4 | c.1089C>G p.S363R | Missense Mutation (SNP) | VAF 30/958 reads (3%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2
- AGO3 | c.2422C>T p.H808Y | Missense Mutation (SNP) | VAF 25/428 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2
- AHCY | c.862G>C p.E288Q | Missense Mutation (SNP) | VAF 20/653 reads (3%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.015); called by muse, mutect2
- AKNAD1 | c.2023A>G p.T675A | Missense Mutation (SNP) | VAF 24/264 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2
- AMBN | c.913G>T p.E305* | Nonsense Mutation (SNP) | VAF 24/526 reads (5%) | called by muse, mutect2
- ANKRD13B | c.724C>G p.Q242E | Missense Mutation (SNP) | VAF 12/240 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.407); called by muse, mutect2
- ANKRD17 | c.3049C>G p.Q1017E | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.93); called by muse, mutect2
- ANKRD30A | c.3641C>G p.T1214R (on ENST00000611781; = p.T1158R on NM_052997.2) | Missense Mutation (SNP) | VAF 18/238 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.014); called by muse, mutect2
- ANKRD31 | c.4953G>A p.M1651I | Missense Mutation (SNP) | VAF 10/235 reads (4%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2
- ARHGAP11A | c.1563G>C p.W521C | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, mutect2
- ARHGAP9 | c.1446G>C p.E482D (on ENST00000393797 / NM_001319850.2; = p.E463D on NM_032496.4) | Missense Mutation (SNP) | VAF 17/298 reads (6%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.672); called by muse, mutect2
- ARID1B | c.70G>C p.A24P | Missense Mutation (SNP) | VAF 15/219 reads (7%) | SIFT deleterious, low confidence (0); called by muse, mutect2
- ARID1B | c.6080A>G p.Y2027C | Missense Mutation (SNP) | VAF 16/306 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ATF7IP2 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 18/310 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.188); called by muse, mutect2
- ATP1A3 | c.1533G>T p.K511N (on ENST00000545399 / NM_001256214.2; = p.K498N on NM_152296.5) | Missense Mutation (SNP) | VAF 13/233 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ATP2B3 | c.3622A>G p.S1208G | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); called by muse, varscan2
- AURKB | c.56C>G p.S19C | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2
- BACE1 | c.948G>C p.E316D | Missense Mutation (SNP) | VAF 11/170 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.207); called by muse, mutect2
- BAG1 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 18/296 reads (6%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); called by muse, mutect2
- BCKDK | c.133G>T p.E45* | Nonsense Mutation (SNP) | VAF 12/210 reads (6%) | called by muse, mutect2
- BMPR2 | c.54C>G p.I18M | Missense Mutation (SNP) | VAF 42/606 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.009); called by muse, mutect2
- C12orf57 | c.319C>G p.L107V | Missense Mutation (SNP) | VAF 44/506 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); called by muse, mutect2
- C12orf71 | c.308C>G p.S103* | Nonsense Mutation (SNP) | VAF 10/244 reads (4%) | called by muse, mutect2
- C6 | c.1812G>C p.E604D | Missense Mutation (SNP) | VAF 17/333 reads (5%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.532); called by muse, mutect2
- CADPS | c.3917T>A p.L1306Q | Missense Mutation (SNP) | VAF 27/208 reads (13%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CAMSAP2 | c.1996G>A p.G666S (on ENST00000236925 / NM_001297707.2; = p.G655S on NM_203459.3) | Missense Mutation (SNP) | VAF 20/258 reads (8%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2
- CAMSAP2 | c.1997G>T p.G666V (on ENST00000236925 / NM_001297707.2; = p.G655V on NM_203459.3) | Missense Mutation (SNP) | VAF 20/258 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.011); called by muse, mutect2
- CAPN5 | c.816C>G p.I272M (on ENST00000456580; = p.I232M on NM_004055.5) | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- CAPRIN2 | c.3226C>T p.Q1076* | Nonsense Mutation (SNP) | VAF 5/44 reads (11%) | called by muse, mutect2, varscan2
- CCAR1 | c.925G>C p.D309H | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.741); called by muse, mutect2
- CCDC15 | c.808G>C p.E270Q | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.646); called by muse, mutect2
- CCDC168 | c.16772C>G p.S5591* | Nonsense Mutation (SNP) | VAF 9/153 reads (6%) | called by muse, mutect2
- CCDC168 | c.8916T>A p.D2972E | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- CDC20 | c.757T>A p.W253R | Missense Mutation (SNP) | VAF 34/318 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.635); called by muse, mutect2
- CDC20 | c.758G>T p.W253L | Missense Mutation (SNP) | VAF 34/325 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2
- CDC25A | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 14/224 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.648); called by muse, mutect2
- CDC27 | c.152C>G p.S51* | Nonsense Mutation (SNP) | VAF 16/281 reads (6%) | called by muse, mutect2
- CDHR3 | c.1052G>C p.S351T | Missense Mutation (SNP) | VAF 22/376 reads (6%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.824); called by muse, mutect2
- CDK11B | c.1674C>G p.I558M | Missense Mutation (SNP) | VAF 25/438 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- CDK15 | c.901C>A p.P301T (on ENST00000652192 / NM_001366386.2; = p.P250T on NM_139158.2) | Missense Mutation (SNP) | VAF 23/290 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); called by muse, mutect2
- CDKN3 | c.524G>C p.R175T | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); called by muse, mutect2
- CEACAM16 | c.604G>C p.E202Q | Missense Mutation (SNP) | VAF 19/165 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); called by muse, mutect2
- CEP162 | c.1130G>C p.R377T | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.022); called by muse, mutect2
- CEP57L1 | c.577G>C p.E193Q | Missense Mutation (SNP) | VAF 15/154 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); called by muse, mutect2
- CERS3 | c.819C>G p.I273M | Missense Mutation (SNP) | VAF 26/176 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- CERT1 | c.196C>G p.R66G | Missense Mutation (SNP) | VAF 12/254 reads (5%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); called by muse, mutect2
- CGRRF1 | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 16/435 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.023); called by muse, mutect2
- CHD3 | c.2821C>G p.L941V | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CHRM3 | c.343C>A p.L115M | Missense Mutation (SNP) | VAF 28/296 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CHST8 | c.1115G>C p.R372P | Missense Mutation (SNP) | VAF 41/436 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.837); called by muse, mutect2
- CLDN16 | c.520C>G p.L174V | Missense Mutation (SNP) | VAF 17/391 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0.018); called by muse, mutect2
- CNTNAP3 | c.2725C>G p.R909G | Missense Mutation (SNP) | VAF 17/205 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- COL4A2 | c.685-2A>G p.X229_splice | Splice Site (SNP) | VAF 21/209 reads (10%) | called by muse, mutect2, varscan2
- COL6A3 | c.1765C>G p.Q589E | Missense Mutation (SNP) | VAF 31/386 reads (8%) | SIFT tolerated (0.88); PolyPhen benign (0); called by muse, mutect2
- COL6A5 | c.1447G>A p.V483I | Missense Mutation (SNP) | VAF 15/268 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.604); called by muse, mutect2
- COQ10B | c.81_82dup p.Q28Rfs*11 | Frame Shift Ins (INS) | VAF 16/180 reads (9%) | called by mutect2, pindel
- CRAMP1 | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- CRTC1 | c.287G>T p.R96L | Missense Mutation (SNP) | VAF 18/386 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2
- CSE1L | c.1597C>T p.R533* | Nonsense Mutation (SNP) | VAF 12/180 reads (7%) | called by muse, mutect2
- CTNNA1 | c.2475G>C p.L825F | Missense Mutation (SNP) | VAF 14/228 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CTNND2 | c.2609T>A p.L870Q | Missense Mutation (SNP) | VAF 11/175 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CTTNBP2NL | c.604G>C p.E202Q | Missense Mutation (SNP) | VAF 19/258 reads (7%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.831); called by muse, mutect2
- CYP11B1 | c.679C>A p.L227M | Missense Mutation (SNP) | VAF 75/1020 reads (7%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); called by muse, mutect2
- CYRIB | c.292C>G p.Q98E | Missense Mutation (SNP) | VAF 20/252 reads (8%) | SIFT tolerated (0.77); PolyPhen benign (0.042); called by muse, mutect2
- DCAF10 | c.239C>G p.S80* | Nonsense Mutation (SNP) | VAF 15/304 reads (5%) | called by muse, mutect2
- DCAF4L2 | c.462C>G p.S154R | Missense Mutation (SNP) | VAF 16/406 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.391); called by muse, mutect2
- DCAF8L1 | c.1535C>T p.A512V | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- DDAH1 | c.616G>C p.D206H | Missense Mutation (SNP) | VAF 10/171 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.201); called by muse, mutect2
- DDX42 | c.1088G>A p.G363E | Missense Mutation (SNP) | VAF 14/362 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- DENND4B | c.1620G>C p.E540D | Missense Mutation (SNP) | VAF 10/238 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.112); called by muse, mutect2
- DEPDC5 | c.750C>G p.F250L | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2
- DGKZ | c.2365G>C p.D789H (on ENST00000454345 / NM_001105540.2; = p.D601H on NM_003646.4) | Missense Mutation (SNP) | VAF 34/567 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DHRS11 | c.408G>A p.M136I | Missense Mutation (SNP) | VAF 20/384 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); called by muse, mutect2
- DHX37 | c.162G>C p.K54N | Missense Mutation (SNP) | VAF 20/408 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2
- DNAAF3 | c.154C>G p.L52V (on ENST00000524407 / NM_001256715.2; = p.L99V on NM_178837.4) | Missense Mutation (SNP) | VAF 32/684 reads (5%) | SIFT tolerated (0.64); PolyPhen benign (0.015); called by muse, mutect2
- DNAH14 | c.4009C>G p.L1337V (on ENST00000445597; = p.L1742V on NM_001367479.1) | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.087); called by muse, mutect2
- DNAH5 | c.12816C>G p.F4272L | Missense Mutation (SNP) | VAF 19/476 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.923); called by muse, mutect2
- DNAJC6 | c.1468G>T p.A490S | Missense Mutation (SNP) | VAF 10/119 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.005); called by muse, mutect2
- DNHD1 | c.8785G>C p.D2929H | Missense Mutation (SNP) | VAF 18/434 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.753); called by muse, mutect2
- DOCK2 | c.4114G>C p.E1372Q | Missense Mutation (SNP) | VAF 14/240 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2
- DPP6 | c.440A>T p.E147V (on ENST00000377770 / NM_001364500.2; = p.E85V on NM_001936.5) | Missense Mutation (SNP) | VAF 26/282 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.567); called by muse, mutect2
- DRGX | c.61T>A p.S21T | Missense Mutation (SNP) | VAF 14/322 reads (4%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, mutect2
- ECHDC1 | c.722C>T p.S241F (on ENST00000531967 / NM_001139510.1; = p.S235F on NM_001002030.2) | Missense Mutation (SNP) | VAF 25/202 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- EIF3L | c.1520C>G p.S507* | Nonsense Mutation (SNP) | VAF 8/154 reads (5%) | called by muse, mutect2
- EPHA6 | c.386-1G>T p.X129_splice | Splice Site (SNP) | VAF 8/159 reads (5%) | called by muse, mutect2
- FAM13B | c.2368G>A p.E790K | Missense Mutation (SNP) | VAF 10/131 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2
- FAM155A | c.1180G>C p.E394Q | Missense Mutation (SNP) | VAF 23/515 reads (4%) | SIFT tolerated (0.41); PolyPhen benign (0.001); called by muse, mutect2
- FAM166B | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 20/512 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.005); called by muse, mutect2
- FAM171B | c.2455G>T p.E819* | Nonsense Mutation (SNP) | VAF 15/87 reads (17%) | called by muse, mutect2
- FAM227A | c.158C>G p.S53C | Missense Mutation (SNP) | VAF 11/249 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- FAM32A | c.198G>C p.E66D | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0.365); called by muse, mutect2
- FANCM | c.4223-1G>A p.X1408_splice | Splice Site (SNP) | VAF 6/108 reads (6%) | called by muse, mutect2
- FAT3 | c.5074C>G p.L1692V | Missense Mutation (SNP) | VAF 10/195 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.108); called by muse, mutect2
- FAT4 | c.14529T>G p.D4843E | Missense Mutation (SNP) | VAF 16/270 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.015); called by muse, mutect2
- FBXO36 | c.474G>C p.W158C | Missense Mutation (SNP) | VAF 20/330 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- FCHSD2 | c.847C>G p.L283V | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.024); called by muse, mutect2
- FHAD1 | c.2577G>C p.Q859H | Missense Mutation (SNP) | VAF 12/260 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); called by muse, mutect2
- FLG | c.8758C>G p.Q2920E | Missense Mutation (SNP) | VAF 30/1200 reads (3%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2
- FNDC3B | c.18G>A p.M6I | Missense Mutation (SNP) | VAF 33/311 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- FOXJ2 | c.811C>G p.Q271E | Missense Mutation (SNP) | VAF 12/322 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.075); called by muse, mutect2
- FRG2C | c.175C>A p.Q59K | Missense Mutation (SNP) | VAF 32/761 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.031); called by muse, mutect2
- FZD1 | c.1755G>C p.Q585H | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2
- GABRP | c.1207G>T p.V403F | Missense Mutation (SNP) | VAF 13/352 reads (4%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2
- GABRR1 | c.224C>T p.S75L | Missense Mutation (SNP) | VAF 8/181 reads (4%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.506); called by muse, mutect2
- GDA | c.890C>G p.S297C | Missense Mutation (SNP) | VAF 16/266 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2
- GEMIN5 | c.3619G>A p.D1207N | Missense Mutation (SNP) | VAF 14/198 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); called by muse, mutect2
- GFM1 | c.483G>C p.Q161H | Missense Mutation (SNP) | VAF 28/704 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GLG1 | c.1819G>T p.G607* | Nonsense Mutation (SNP) | VAF 30/306 reads (10%) | called by muse, mutect2
- GLG1 | c.256C>T p.Q86* | Nonsense Mutation (SNP) | VAF 39/309 reads (13%) | called by muse, mutect2, varscan2
- GLRA3 | c.828G>A p.W276* | Nonsense Mutation (SNP) | VAF 15/249 reads (6%) | called by muse, mutect2
- GOLGA8T | c.1198G>T p.E400* | Nonsense Mutation (SNP) | VAF 41/651 reads (6%) | called by muse, mutect2
- GRIA1 | c.589G>C p.E197Q | Missense Mutation (SNP) | VAF 11/162 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.307); called by muse, mutect2
- GUCY1A1 | c.151C>G p.P51A | Missense Mutation (SNP) | VAF 16/452 reads (4%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0); called by muse, mutect2
- H3C10 | c.84G>C p.K28N | Missense Mutation (SNP) | VAF 20/356 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.093); called by muse, mutect2
- H3C10 | c.265G>C p.A89P | Missense Mutation (SNP) | VAF 22/448 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2
- HECTD4 | c.6098C>G p.S2033C | Missense Mutation (SNP) | VAF 34/646 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.473); called by muse, mutect2
- HECW1 | c.1891G>T p.G631C | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- HEPH | c.76C>G p.R26G (on ENST00000343002; = p.R80G on NM_138737.5) | Missense Mutation (SNP) | VAF 10/193 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HHATL | c.242C>G p.S81C | Missense Mutation (SNP) | VAF 10/220 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2
- HIVEP2 | c.3798G>C p.K1266N | Missense Mutation (SNP) | VAF 18/439 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.015); called by muse, mutect2
- HIVEP3 | c.343G>C p.E115Q | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- HLCS | c.409A>T p.S137C | Missense Mutation (SNP) | VAF 34/620 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, mutect2
- HOXD1 | c.402_405del p.Y134* | Frame Shift Del (DEL) | VAF 25/233 reads (11%) | called by mutect2, pindel, varscan2
- HSPA13 | c.8G>C p.R3T | Missense Mutation (SNP) | VAF 19/309 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2
- HSPE1 | c.275G>T p.R92I | Missense Mutation (SNP) | VAF 15/138 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- HUWE1 | c.8293C>G p.L2765V | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.034); called by muse, mutect2
- HUWE1 | c.8171C>G p.S2724C | Missense Mutation (SNP) | VAF 19/195 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- HUWE1 | c.4344C>A p.F1448L | Missense Mutation (SNP) | VAF 13/181 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- IBTK | c.5G>T p.S2I | Missense Mutation (SNP) | VAF 11/121 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.174); called by muse, mutect2
- ICAM5 | c.2481C>G p.I827M | Missense Mutation (SNP) | VAF 14/183 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ICE2 | c.-95G>C | Splice Region (SNP) | VAF 34/330 reads (10%) | called by muse, mutect2, varscan2
- IGHV1-58 | c.77C>T p.S26F | Missense Mutation (SNP) | VAF 24/406 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); called by muse, mutect2
- IGSF10 | c.2870C>T p.S957F | Missense Mutation (SNP) | VAF 10/220 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.754); called by muse, mutect2
- IL10RA | c.1576C>A p.L526M | Missense Mutation (SNP) | VAF 30/470 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2
- IL10RB | c.112C>G p.L38V | Missense Mutation (SNP) | VAF 18/372 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IL20RB | c.499G>T p.V167L | Missense Mutation (SNP) | VAF 22/378 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.279); called by muse, mutect2
- IL23R | c.1696T>A p.S566T | Missense Mutation (SNP) | VAF 36/477 reads (8%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.736); called by muse, mutect2
- ILF3 | c.1806G>C p.K602N | Missense Mutation (SNP) | VAF 30/390 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2
- ILRUN | c.667G>C p.D223H (on ENST00000374023 / NM_024294.4; = p.D157H on NM_022758.6) | Missense Mutation (SNP) | VAF 16/383 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.482); called by muse, mutect2
- IMPDH2 | c.432C>G p.I144M | Missense Mutation (SNP) | VAF 28/580 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.814); called by muse, mutect2
- INPP5B | c.2365C>G p.H789D (on ENST00000373023; = p.H709D on NM_005540.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/414 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.142); called by muse, mutect2
- IQSEC3 | c.2076G>C p.Q692H (on ENST00000538872 / NM_001170738.2; = p.Q389H on NM_015232.1) | Missense Mutation (SNP) | VAF 26/338 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.127); called by muse, mutect2
- ITPR2 | c.7438G>C p.D2480H | Missense Mutation (SNP) | VAF 10/266 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- JADE1 | c.1613G>T p.R538I | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0.003); called by muse, mutect2
- JAKMIP3 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 24/616 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- JMY | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- JOSD1 | c.526C>T p.H176Y | Missense Mutation (SNP) | VAF 12/264 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.022); called by muse, mutect2
- JPH2 | c.1146G>C p.Q382H | Missense Mutation (SNP) | VAF 22/361 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); called by muse, mutect2
- KCNC4 | c.446G>A p.R149Q | Missense Mutation (SNP) | VAF 28/488 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.266); called by muse, mutect2
- KCTD6 | c.224C>T p.S75L | Missense Mutation (SNP) | VAF 9/142 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.405); called by muse, mutect2
- KDM2B | c.2869G>A p.E957K | Missense Mutation (SNP) | VAF 16/484 reads (3%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.489); called by muse, mutect2
- KIAA1109 | c.1053-2A>G p.X351_splice | Splice Site (SNP) | VAF 10/132 reads (8%) | called by muse, mutect2
- KIF4B | c.407T>A p.L136Q | Missense Mutation (SNP) | VAF 19/368 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2
- KLHL40 | c.1238C>A p.S413Y | Missense Mutation (SNP) | VAF 42/542 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- KPNA7 | c.706G>T p.D236Y | Missense Mutation (SNP) | VAF 51/435 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0.286); called by muse, mutect2, varscan2
- KRT33B | c.1091A>G p.D364G | Missense Mutation (SNP) | VAF 10/241 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- LAMB1 | c.2627G>A p.C876Y | Missense Mutation (SNP) | VAF 16/324 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- LAMB3 | c.2089C>T p.Q697* | Nonsense Mutation (SNP) | VAF 33/592 reads (6%) | called by muse, mutect2
- LCAT | c.181G>T p.E61* | Nonsense Mutation (SNP) | VAF 24/584 reads (4%) | called by muse, mutect2
- LRIG1 | c.2549C>T p.S850F | Missense Mutation (SNP) | VAF 10/318 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- LRRC10 | c.363G>C p.Q121H | Missense Mutation (SNP) | VAF 14/197 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); called by muse, mutect2
- LRRC14 | c.694C>G p.L232V | Missense Mutation (SNP) | VAF 21/432 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); called by muse, mutect2
- LRRC37B | c.1502C>G p.S501* | Nonsense Mutation (SNP) | VAF 17/416 reads (4%) | called by muse, mutect2
- LRRC49 | c.652C>G p.L218V | Missense Mutation (SNP) | VAF 10/191 reads (5%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.51); called by muse, mutect2
- LRRN4 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 51/548 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2
- LRRTM2 | c.608G>C p.G203A | Missense Mutation (SNP) | VAF 21/325 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- M6PR | c.544G>T p.E182* | Nonsense Mutation (SNP) | VAF 35/365 reads (10%) | called by muse, mutect2
- MAGOH | c.379C>T p.Q127* | Nonsense Mutation (SNP) | VAF 16/188 reads (9%) | called by muse, mutect2
- MAP2K7 | c.97G>C p.D33H | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.455); called by muse, mutect2
- MAP3K10 | c.2302G>A p.E768K | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.033); called by muse, mutect2
- MAP3K11 | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 9/204 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.079); called by muse, mutect2
- MARCHF2 | c.664G>A p.D222N | Missense Mutation (SNP) | VAF 18/270 reads (7%) | SIFT tolerated (0.49); PolyPhen benign (0.015); called by muse, mutect2
- MCM10 | c.790G>A p.E264K (on ENST00000484800 / NM_182751.3; = p.E263K on NM_018518.5) | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); called by muse, mutect2
- MCM10 | c.1802G>C p.R601T (on ENST00000484800 / NM_182751.3; = p.R600T on NM_018518.5) | Missense Mutation (SNP) | VAF 17/348 reads (5%) | SIFT tolerated (0.57); PolyPhen benign (0.124); called by muse, mutect2
- MCMBP | c.1921G>A p.E641K | Missense Mutation (SNP) | VAF 8/163 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.985); called by muse, mutect2
- MCMDC2 | c.623T>G p.I208R | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.188); called by muse, mutect2
- MDC1 | c.5846C>T p.S1949F | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- MED13 | c.1115C>T p.A372V | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.996); called by muse, mutect2
- MESD | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 33/266 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- MGAT3 | c.1016C>A p.P339H | Missense Mutation (SNP) | VAF 37/349 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MINK1 | c.3525G>C p.Q1175H | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- MKRN1 | c.704C>T p.S235F | Missense Mutation (SNP) | VAF 15/416 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.091); called by muse, mutect2
- MMP24 | c.655G>C p.D219H | Missense Mutation (SNP) | VAF 24/550 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- MMP28 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 9/136 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2
- MPST | c.639C>G p.F213L (on ENST00000341116 / NM_001369904.2; = p.F233L on NM_021126.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); called by muse, mutect2
- MROH5 | c.1830G>A p.M610I | Missense Mutation (SNP) | VAF 17/414 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.012); called by muse, mutect2
- MRPL11 | c.223G>C p.D75H | Missense Mutation (SNP) | VAF 12/269 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MRPL45 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 24/352 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.255); called by muse, mutect2
- MRPS28 | c.416G>T p.R139M | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); called by muse, mutect2
- MRPS31 | c.727G>A p.D243N | Missense Mutation (SNP) | VAF 30/249 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MTFR1 | c.922G>C p.E308Q | Missense Mutation (SNP) | VAF 23/474 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.439); called by muse, mutect2
- MYBBP1A | c.2134G>T p.D712Y | Missense Mutation (SNP) | VAF 13/294 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2
- MYH13 | c.4814T>A p.L1605Q | Missense Mutation (SNP) | VAF 24/436 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- MYH6 | c.1506C>G p.Y502* | Nonsense Mutation (SNP) | VAF 43/675 reads (6%) | called by muse, mutect2
- MYO15A | c.7196T>G p.L2399R | Missense Mutation (SNP) | VAF 21/366 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- MYO3A | c.4051G>T p.V1351L | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.011); called by muse, mutect2
- MYO9B | c.5490C>G p.V1830= | Splice Region (SNP) | VAF 27/437 reads (6%) | called by muse, mutect2
- MYT1 | c.1407G>T p.K469N | Missense Mutation (SNP) | VAF 23/174 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYT1 | c.2395A>T p.T799S | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.24); called by muse, mutect2
- NAA25 | c.1948G>C p.E650Q | Missense Mutation (SNP) | VAF 18/248 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.038); called by muse, mutect2
- NCKAP1L | c.1742A>G p.E581G | Missense Mutation (SNP) | VAF 22/328 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.22); called by muse, mutect2
- NCOR1 | c.6011-1G>C p.X2004_splice | Splice Site (SNP) | VAF 16/224 reads (7%) | called by muse, mutect2
- NEK5 | c.966G>C p.R322S | Missense Mutation (SNP) | VAF 18/274 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.115); called by muse, mutect2
- NELL1 | c.1271C>T p.S424F | Missense Mutation (SNP) | VAF 11/218 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); called by muse, mutect2
- NEUROD6 | c.755C>A p.A252D | Missense Mutation (SNP) | VAF 17/361 reads (5%) | SIFT tolerated (0.66); PolyPhen benign (0.028); called by muse, mutect2
- NFIB | c.832G>C p.D278H | Missense Mutation (SNP) | VAF 20/214 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.683); called by muse, mutect2
- NLRC4 | c.1069C>T p.H357Y | Missense Mutation (SNP) | VAF 22/344 reads (6%) | SIFT tolerated (0.43); PolyPhen benign (0.377); called by muse, mutect2
- NLRP8 | c.542G>C p.G181A | Missense Mutation (SNP) | VAF 35/406 reads (9%) | SIFT tolerated (0.68); PolyPhen benign (0.003); called by muse, mutect2
- NOS1 | c.3583C>A p.L1195I | Missense Mutation (SNP) | VAF 11/182 reads (6%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.903); called by muse, mutect2
- NOX3 | c.1478G>A p.W493* | Nonsense Mutation (SNP) | VAF 20/238 reads (8%) | called by muse, mutect2
- NR0B2 | c.686C>A p.T229N | Missense Mutation (SNP) | VAF 22/428 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.072); called by muse, mutect2
- NRDC | c.2488C>G p.R830G | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.031); called by muse, mutect2
- NUBPL | c.637A>T p.I213F | Missense Mutation (SNP) | VAF 42/513 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); called by muse, mutect2
- NUDT10 | c.385C>T p.L129F | Missense Mutation (SNP) | VAF 14/256 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NYNRIN | c.4557G>C p.E1519D | Missense Mutation (SNP) | VAF 21/324 reads (6%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.007); called by muse, mutect2
- OPN4 | c.190G>C p.D64H | Missense Mutation (SNP) | VAF 12/333 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- OR13C3 | c.900A>T p.E300D | Missense Mutation (SNP) | VAF 36/350 reads (10%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR2J2 | c.31G>T p.D11Y | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- OR2T11 | c.106G>T p.V36L | Missense Mutation (SNP) | VAF 28/402 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- OR2T33 | c.889G>T p.G297* | Nonsense Mutation (SNP) | VAF 27/235 reads (11%) | called by muse, mutect2, varscan2
- OR4P4 | c.884C>A p.A295D | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- OR5AP2 | c.565C>A p.P189T | Missense Mutation (SNP) | VAF 9/146 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- OTOP3 | c.116G>A p.R39K | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated (0.82); PolyPhen benign (0.015); called by muse, mutect2
- OTUD4 | c.1966C>G p.Q656E (on ENST00000447906 / NM_001366057.1; = p.Q591E on NM_001102653.1) | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2
- PATJ | c.1752G>A p.M584I | Missense Mutation (SNP) | VAF 15/231 reads (6%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); called by muse, mutect2
- PAX7 | c.761C>A p.T254N | Missense Mutation (SNP) | VAF 13/312 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.243); called by muse, mutect2
- PCDH11X | c.3555C>A p.H1185Q | Missense Mutation (SNP) | VAF 66/454 reads (15%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PCDHA8 | c.422T>G p.F141C | Missense Mutation (SNP) | VAF 30/541 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.944); called by muse, mutect2
- PCDHA9 | c.1543G>A p.G515S | Missense Mutation (SNP) | VAF 59/1035 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PCDHGB3 | c.2256C>A p.Y752* | Nonsense Mutation (SNP) | VAF 12/236 reads (5%) | called by muse, mutect2
- PCDHGC3 | c.1264G>C p.E422Q | Missense Mutation (SNP) | VAF 13/279 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.752); called by muse, mutect2
- PCSK2 | c.127G>C p.E43Q | Missense Mutation (SNP) | VAF 13/157 reads (8%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2
- PCSK5 | c.2785G>C p.E929Q | Missense Mutation (SNP) | VAF 11/234 reads (5%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2
- PCSK6 | c.917G>A p.W306* | Nonsense Mutation (SNP) | VAF 27/342 reads (8%) | called by muse, mutect2
- PDE3A | c.2447G>A p.C816Y | Missense Mutation (SNP) | VAF 21/335 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.312); called by muse, mutect2
- PDIA5 | c.701+1G>T p.X234_splice | Splice Site (SNP) | VAF 16/230 reads (7%) | called by muse, mutect2
- PELP1 | c.1615C>G p.L539V | Missense Mutation (SNP) | VAF 19/362 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.021); called by muse, mutect2
- PIGB | c.104G>A p.R35Q | Missense Mutation (SNP) | VAF 32/284 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- PIK3C3 | c.2626G>T p.E876* | Nonsense Mutation (SNP) | VAF 16/206 reads (8%) | called by muse, mutect2
- PKD1 | c.8174A>T p.H2725L | Missense Mutation (SNP) | VAF 74/835 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- PLA2G4F | c.418C>A p.P140T | Missense Mutation (SNP) | VAF 10/224 reads (4%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.469); called by muse, mutect2
- PLAG1 | c.1430C>A p.S477* | Nonsense Mutation (SNP) | VAF 13/110 reads (12%) | called by muse, mutect2, varscan2
- PLCG1 | c.2008C>T p.H670Y | Missense Mutation (SNP) | VAF 34/263 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- PLEKHA5 | c.1160G>C p.R387T | Missense Mutation (SNP) | VAF 15/458 reads (3%) | SIFT tolerated (0.27); PolyPhen benign (0.142); called by muse, mutect2
- PLEKHA5 | c.2732G>C p.R911T | Missense Mutation (SNP) | VAF 13/393 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- PLEKHG1 | c.1718C>G p.S573C | Missense Mutation (SNP) | VAF 13/245 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PLEKHG6 | c.655C>T p.H219Y | Missense Mutation (SNP) | VAF 22/220 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2
- PLPP7 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.391); called by muse, mutect2
- PLVAP | c.487C>G p.Q163E | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT tolerated (0.88); PolyPhen benign (0.022); called by muse, mutect2
- PLXNA2 | c.5164G>A p.E1722K | Missense Mutation (SNP) | VAF 14/254 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2
- PLXNA4 | c.4245G>C p.K1415N | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2
- PNPLA4 | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- POGLUT3 | c.1258C>G p.L420V | Missense Mutation (SNP) | VAF 12/238 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- POLQ | c.7748G>T p.G2583V | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- POLR1B | c.2740C>A p.L914M | Missense Mutation (SNP) | VAF 19/210 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- POLR2A | c.1335+1G>T p.X445_splice | Splice Site (SNP) | VAF 13/188 reads (7%) | called by muse, mutect2
- PPIG | c.1086G>C p.W362C | Missense Mutation (SNP) | VAF 17/164 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.012); called by muse, mutect2
- PRAME | c.239G>T p.C80F | Missense Mutation (SNP) | VAF 14/246 reads (6%) | SIFT tolerated (0.7); PolyPhen benign (0.374); called by muse, mutect2
- PRB3 | c.203C>T p.S68F | Missense Mutation (SNP) | VAF 28/470 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2
- PRDM15 | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 22/494 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.022); called by muse, mutect2
- PRDM7 | c.243C>G p.I81M | Missense Mutation (SNP) | VAF 27/406 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.021); called by muse, mutect2
- PRICKLE3 | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PRKCE | c.860A>G p.N287S | Missense Mutation (SNP) | VAF 14/264 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.846); called by muse, mutect2
- PRKD1 | c.1072G>A p.D358N | Missense Mutation (SNP) | VAF 22/574 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.067); called by muse, mutect2
- PRPF8 | c.2701C>G p.L901V | Missense Mutation (SNP) | VAF 38/596 reads (6%) | SIFT tolerated (0.48); PolyPhen benign (0.196); called by muse, mutect2
- PRR5 | c.85G>C p.E29Q (on ENST00000336985 / NM_181333.4; = p.E20Q on NM_015366.4) | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- PRUNE2 | c.2695G>C p.D899H | Missense Mutation (SNP) | VAF 14/268 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2
- PSG7 | c.892C>T p.P298S | Missense Mutation (SNP) | VAF 22/638 reads (3%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.913); called by muse, mutect2
- PTPN13 | c.1124C>G p.S375* | Nonsense Mutation (SNP) | VAF 12/198 reads (6%) | called by muse, mutect2
- PTPN2 | c.886G>C p.D296H | Missense Mutation (SNP) | VAF 12/234 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.12); called by muse, mutect2
- PUSL1 | c.163G>T p.E55* | Nonsense Mutation (SNP) | VAF 15/253 reads (6%) | called by muse, mutect2
- PVR | c.897C>G p.I299M | Missense Mutation (SNP) | VAF 28/348 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); called by muse, mutect2
- PXDN | c.3477C>G p.I1159M | Missense Mutation (SNP) | VAF 18/348 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); called by muse, mutect2
- PYHIN1 | c.740C>A p.T247K | Missense Mutation (SNP) | VAF 22/221 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- RAB30 | c.469G>C p.D157H | Missense Mutation (SNP) | VAF 24/408 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.941); called by muse, mutect2
- RAB33B | c.246C>G p.I82M | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- RAI1 | c.5209G>C p.E1737Q | Missense Mutation (SNP) | VAF 24/331 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.419); called by muse, mutect2
- RAPGEF2 | c.2024T>C p.L675P | Missense Mutation (SNP) | VAF 13/138 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RETSAT | c.1071C>G p.F357L | Missense Mutation (SNP) | VAF 26/311 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2
- RHOBTB1 | c.805C>G p.L269V | Missense Mutation (SNP) | VAF 28/420 reads (7%) | SIFT tolerated (0.56); PolyPhen benign (0.034); called by muse, mutect2
- RNASEH1 | c.216G>T p.R72S | Missense Mutation (SNP) | VAF 13/200 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.073); called by muse, mutect2
- RNF135 | c.406C>G p.Q136E | Missense Mutation (SNP) | VAF 57/504 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RNF141 | c.602C>G p.S201C | Missense Mutation (SNP) | VAF 10/206 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); called by muse, mutect2
- RNF146 | c.379G>A p.D127N (on ENST00000368314 / NM_001242850.2; = p.D126N on NM_030963.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- RNF146 | c.994G>A p.D332N (on ENST00000368314 / NM_001242850.2; = p.D331N on NM_030963.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0); called by mutect2, varscan2
- RNF26 | c.1045C>G p.P349A | Missense Mutation (SNP) | VAF 30/305 reads (10%) | SIFT tolerated (0.87); PolyPhen benign (0); called by muse, mutect2
- ROBO2 | c.4072A>C p.S1358R | Missense Mutation (SNP) | VAF 22/312 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.112); called by muse, mutect2
- RORC | c.619G>C p.E207Q | Missense Mutation (SNP) | VAF 19/456 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2
- RPRD2 | c.2821G>T p.D941Y | Missense Mutation (SNP) | VAF 11/238 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- RXFP2 | c.1735G>T p.D579Y | Missense Mutation (SNP) | VAF 29/212 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- RXRB | c.1099G>A p.D367N | Missense Mutation (SNP) | VAF 26/292 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RYR2 | c.4985C>G p.S1662* | Nonsense Mutation (SNP) | VAF 22/232 reads (9%) | called by muse, mutect2
- SACS | c.8853dup p.V2952Cfs*15 | Frame Shift Ins (INS) | VAF 12/95 reads (13%) | called by mutect2, pindel, varscan2
- SAXO2 | c.407C>T p.S136F | Missense Mutation (SNP) | VAF 27/347 reads (8%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.524); called by muse, mutect2
- SCN8A | c.5627C>G p.S1876C | Missense Mutation (SNP) | VAF 22/704 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); called by muse, mutect2
- SCN9A | c.2677A>T p.K893* (on ENST00000303354; = p.K882* on NM_002977.3) | Nonsense Mutation (SNP) | VAF 35/485 reads (7%) | called by muse, mutect2
- SEC62 | c.364G>C p.D122H | Missense Mutation (SNP) | VAF 11/262 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2
- SEPSECS | c.18C>G p.F6L | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2
- SERTAD4 | c.850G>C p.E284Q | Missense Mutation (SNP) | VAF 14/243 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.169); called by muse, mutect2
- SLC12A9 | c.1442C>T p.S481F | Missense Mutation (SNP) | VAF 15/349 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- SLC22A3 | c.1096C>G p.Q366E | Missense Mutation (SNP) | VAF 25/742 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- SLC30A3 | c.110C>G p.P37R | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.063); called by muse, mutect2
- SLC6A11 | c.103C>G p.P35A | Missense Mutation (SNP) | VAF 10/212 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2
- SMYD3 | c.726G>T p.M242I (on ENST00000490107 / NM_001375962.1; = p.M183I on NM_022743.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT tolerated (0.58); PolyPhen benign (0.006); called by muse, mutect2
- SOCS2 | c.140G>A p.G47E | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SOX2 | c.210G>C p.E70D | Missense Mutation (SNP) | VAF 24/774 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2
- SPEF2 | c.3621-1G>C p.X1207_splice | Splice Site (SNP) | VAF 6/80 reads (8%) | called by muse, mutect2
- SPTB | c.1069C>G p.Q357E | Missense Mutation (SNP) | VAF 24/460 reads (5%) | SIFT tolerated (0.73); PolyPhen benign (0.145); called by muse, mutect2
- ST8SIA3 | c.91G>C p.V31L | Missense Mutation (SNP) | VAF 35/575 reads (6%) | PolyPhen possibly damaging (0.872); called by muse, mutect2
- STAT3 | c.1462A>T p.K488* | Nonsense Mutation (SNP) | VAF 10/214 reads (5%) | called by muse, mutect2
- STEAP3 | c.578G>C p.G193A | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- STK26 | c.117C>G p.F39L | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); called by muse, mutect2
- STXBP5L | c.66C>A p.S22R | Missense Mutation (SNP) | VAF 16/308 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.099); called by muse, mutect2
- SUSD1 | c.527-3C>T | Splice Region (SNP) | VAF 16/124 reads (13%) | called by muse, mutect2, varscan2
- SYNE1 | c.15028G>C p.E5010Q (on ENST00000367255 / NM_182961.4; = p.E4939Q on NM_033071.3) | Missense Mutation (SNP) | VAF 23/324 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.015); called by muse, mutect2
- SYNE1 | c.13577A>T p.E4526V (on ENST00000367255 / NM_182961.4; = p.E4455V on NM_033071.3) | Missense Mutation (SNP) | VAF 32/349 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.422); called by muse, mutect2
- SYNE1 | c.12826G>C p.E4276Q (on ENST00000367255 / NM_182961.4; = p.E4205Q on NM_033071.3) | Missense Mutation (SNP) | VAF 23/380 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2
- SZT2 | c.2680G>C p.E894Q | Missense Mutation (SNP) | VAF 18/232 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TADA2A | c.1120G>C p.E374Q | Missense Mutation (SNP) | VAF 12/271 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.452); called by muse, mutect2
- TAS2R13 | c.745C>G p.L249V | Missense Mutation (SNP) | VAF 48/315 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- TBC1D4 | c.1454C>T p.S485L | Missense Mutation (SNP) | VAF 33/298 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- TCF20 | c.614C>G p.S205* | Nonsense Mutation (SNP) | VAF 25/365 reads (7%) | called by muse, mutect2
- TCTN2 | c.443C>T p.S148F | Missense Mutation (SNP) | VAF 24/260 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.483); called by muse, mutect2
- TERB1 | c.1159G>C p.E387Q | Missense Mutation (SNP) | VAF 10/200 reads (5%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.915); called by muse, mutect2
- TGFBR3 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 52/324 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- THBS2 | c.2692C>A p.P898T | Missense Mutation (SNP) | VAF 29/524 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2
- TLN1 | c.3935C>A p.S1312* | Nonsense Mutation (SNP) | VAF 14/365 reads (4%) | called by muse, mutect2
- TLR1 | c.2062G>C p.E688Q | Missense Mutation (SNP) | VAF 21/464 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- TLX1 | c.115C>G p.R39G | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.727); called by muse, mutect2, varscan2
- TMEM132B | c.1000C>A p.Q334K | Missense Mutation (SNP) | VAF 21/366 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0.164); called by muse, mutect2
- TMEM132C | c.571C>A p.L191M | Missense Mutation (SNP) | VAF 18/284 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2
- TMEM252 | c.434C>T p.P145L | Missense Mutation (SNP) | VAF 9/153 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TMPRSS15 | c.1133C>A p.T378N | Missense Mutation (SNP) | VAF 19/314 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); called by muse, mutect2
- TOGARAM1 | c.4963T>C p.W1655R | Missense Mutation (SNP) | VAF 18/332 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TONSL | c.2699C>A p.S900* | Nonsense Mutation (SNP) | VAF 13/244 reads (5%) | called by muse, mutect2
- TOP2A | c.3766G>A p.E1256K | Missense Mutation (SNP) | VAF 10/246 reads (4%) | SIFT tolerated (0.56); PolyPhen benign (0.001); called by muse, mutect2
- TOX3 | c.1579C>G p.Q527E | Missense Mutation (SNP) | VAF 16/246 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.93); called by muse, mutect2
- TRAV12-3 | c.67C>A p.Q23K | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- TRAV18 | c.107C>A p.A36E | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- TRBV2 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 23/324 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.444); called by muse, mutect2
- TRDN | c.1978G>C p.D660H | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.258); called by muse, mutect2
- TRIM37 | c.531G>T p.E177D | Missense Mutation (SNP) | VAF 37/278 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- TRIM43B | c.661C>G p.Q221E | Missense Mutation (SNP) | VAF 28/376 reads (7%) | SIFT tolerated (0.44); PolyPhen benign (0.005); called by muse, mutect2
- TSEN34 | c.796G>C p.E266Q | Missense Mutation (SNP) | VAF 25/340 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0.132); called by muse, mutect2
- TSPAN1 | c.237G>C p.K79N | Missense Mutation (SNP) | VAF 25/611 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, mutect2
- TUBA8 | c.710C>G p.S237* | Nonsense Mutation (SNP) | VAF 34/602 reads (6%) | called by muse, mutect2
- TUBGCP4 | c.151G>C p.D51H | Missense Mutation (SNP) | VAF 20/228 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0.001); called by muse, mutect2
- TYRO3 | c.1359G>C p.K453N | Missense Mutation (SNP) | VAF 28/596 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.122); called by muse, mutect2
- UBAP2 | c.1034A>G p.N345S | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.113); called by muse, mutect2
- UBQLN2 | c.1299C>A p.F433L | Missense Mutation (SNP) | VAF 26/273 reads (10%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.596); called by muse, mutect2
- UMODL1 | c.2302G>C p.E768Q (on ENST00000408910 / NM_001004416.2; = p.E896Q on NM_173568.3) | Missense Mutation (SNP) | VAF 18/283 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.677); called by muse, mutect2
- USP29 | c.1389A>T p.K463N | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); called by muse, mutect2
- USP39 | c.451C>G p.H151D | Missense Mutation (SNP) | VAF 20/184 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2
- USP5 | c.2119C>G p.L707V (on ENST00000229268 / NM_001098536.2; = p.L684V on NM_003481.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated (0.97); PolyPhen benign (0.1); called by muse, mutect2
- VDAC2 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 7/118 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.453); called by muse, mutect2
- VEGFC | c.734C>T p.T245I | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.01); called by muse, mutect2
- VIT | c.410-1G>A p.X137_splice | Splice Site (SNP) | VAF 9/186 reads (5%) | called by muse, mutect2
- VPS13A | c.5608G>A p.D1870N | Missense Mutation (SNP) | VAF 22/294 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.03); called by muse, mutect2
- VPS13D | c.739C>G p.L247V | Missense Mutation (SNP) | VAF 14/328 reads (4%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.885); called by muse, mutect2
- VPS72 | c.670G>C p.E224Q | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.23); called by muse, mutect2
- WNK3 | c.5073+1G>C p.X1691_splice | Splice Site (SNP) | VAF 9/59 reads (15%) | called by mutect2, varscan2
- WNT8A | c.736G>C p.E246Q | Missense Mutation (SNP) | VAF 14/374 reads (4%) | SIFT tolerated (0.34); PolyPhen benign (0.029); called by muse, mutect2
- XIRP1 | c.1290G>C p.Q430H | Missense Mutation (SNP) | VAF 12/276 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.364); called by muse, mutect2
- YIPF3 | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 13/328 reads (4%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.006); called by muse, mutect2
- ZC3HAV1L | c.801G>C p.E267D | Missense Mutation (SNP) | VAF 16/274 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.277); called by muse, mutect2
- ZDHHC7 | c.326C>G p.P109R | Missense Mutation (SNP) | VAF 35/282 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZFHX4 | c.2749C>A p.L917M | Missense Mutation (SNP) | VAF 11/196 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZIC5 | c.58G>C p.D20H | Missense Mutation (SNP) | VAF 50/722 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.788); called by muse, mutect2
- ZMIZ2 | c.1756G>C p.E586Q | Missense Mutation (SNP) | VAF 12/233 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2
- ZNF112 | c.486A>G p.I162M (on ENST00000337401 / NM_001083335.2; = p.I156M on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/351 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.011); called by muse, mutect2
- ZNF227 | c.1251C>G p.F417L | Missense Mutation (SNP) | VAF 16/366 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2
- ZNF227 | c.2278G>C p.E760Q | Missense Mutation (SNP) | VAF 28/380 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ZNF236 | c.1270G>T p.A424S | Missense Mutation (SNP) | VAF 14/397 reads (4%) | SIFT tolerated (0.82); PolyPhen benign (0); called by muse, mutect2
- ZNF292 | c.7406C>T p.S2469L | Missense Mutation (SNP) | VAF 12/183 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2
- ZNF385D | c.1078G>T p.A360S | Missense Mutation (SNP) | VAF 40/490 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0.001); called by muse, mutect2
- ZNF44 | c.1369C>G p.Q457E (on ENST00000356109 / NM_001164276.2; = p.Q409E on NM_016264.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/194 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.174); called by muse, mutect2
- ZNF469 | c.10149G>C p.M3383I (on ENST00000437464; = p.M3411I on NM_001367624.2) | Missense Mutation (SNP) | VAF 10/220 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.856); called by muse, mutect2
- ZNF564 | c.896A>T p.H299L | Missense Mutation (SNP) | VAF 28/482 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF569 | c.239G>C p.G80A | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.981); called by muse, mutect2
- ZNF578 | c.637T>A p.F213I | Missense Mutation (SNP) | VAF 22/344 reads (6%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2
- ZNF678 | c.1109T>C p.I370T | Missense Mutation (SNP) | VAF 14/219 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); called by muse, mutect2
- ZNF703 | c.1650G>C p.K550N | Missense Mutation (SNP) | VAF 39/144 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- ZNF76 | c.1608+8G>C | Splice Region (SNP) | VAF 32/403 reads (8%) | called by muse, mutect2
- ZNRF1 | c.312G>T p.Q104H | Missense Mutation (SNP) | VAF 30/388 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); called by muse, mutect2
- ZSWIM9 | c.1125C>G p.D375E | Missense Mutation (SNP) | VAF 42/694 reads (6%) | SIFT tolerated (0.95); PolyPhen benign (0.086); called by muse, mutect2
- ABCA7 | c.2116C>T p.L706= | Silent (SNP) | VAF 29/364 reads (8%) | called by muse, mutect2
- ABCC2 | c.1407G>A p.V469= | Silent (SNP) | VAF 10/240 reads (4%) | called by muse, mutect2
- ABCD2 | c.744C>T p.S248= | Silent (SNP) | VAF 12/224 reads (5%) | called by muse, mutect2
- ACE | c.750C>A p.L250= | Silent (SNP) | VAF 23/429 reads (5%) | catalogued as COSV52012197, COSV99326991; called by muse, mutect2
- ACTN2 | c.846G>C p.L282= | Silent (SNP) | VAF 24/320 reads (8%) | called by muse, mutect2
- ADAM33 | c.1326C>G p.L442= | Silent (SNP) | VAF 14/296 reads (5%) | called by muse, mutect2
- ADAMTS2 | c.2064C>T p.L688= | Silent (SNP) | VAF 28/558 reads (5%) | catalogued as COSV52381666; called by muse, mutect2
- ADNP | c.3144G>A p.K1048= | Silent (SNP) | VAF 8/143 reads (6%) | called by muse, mutect2
- AFG3L2 | c.867C>T p.F289= | Silent (SNP) | VAF 28/426 reads (7%) | catalogued as rs748162809; called by muse, mutect2
- AGO4 | c.2433A>T p.V811= | Silent (SNP) | VAF 18/440 reads (4%) | called by muse, mutect2
- AHCYL2 | c.219C>G p.L73= | Silent (SNP) | VAF 12/294 reads (4%) | called by muse, mutect2
- AHNAK | c.12756C>T p.I4252= | Silent (SNP) | VAF 18/390 reads (5%) | called by muse, mutect2
- AICDA | c.516C>T p.L172= | Silent (SNP) | VAF 42/358 reads (12%) | called by muse, mutect2, varscan2
- AKAP4 | c.843G>C p.L281= | Silent (SNP) | VAF 21/112 reads (19%) | catalogued as COSV62074563; called by muse, mutect2, varscan2
- ANKH | c.498C>A p.I166= | Silent (SNP) | VAF 22/581 reads (4%) | called by muse, mutect2
- ANXA6 | c.162G>A p.Q54= | Silent (SNP) | VAF 9/157 reads (6%) | called by muse, mutect2
- APEX2 | c.297G>A p.L99= | Silent (SNP) | VAF 8/92 reads (9%) | catalogued as COSV66624276; called by muse, mutect2
- ARHGAP22 | c.1044C>T p.L348= | Silent (SNP) | VAF 23/364 reads (6%) | catalogued as rs1205487742; called by muse, mutect2
- ARHGEF17 | c.630A>G p.P210= | Silent (SNP) | VAF 13/218 reads (6%) | called by muse, mutect2
- ARHGEF33 | c.726C>G p.L242= | Silent (SNP) | VAF 26/257 reads (10%) | catalogued as COSV67256838; called by muse, mutect2, varscan2
- ATP2B4 | c.48G>A p.E16= | Silent (SNP) | VAF 10/164 reads (6%) | called by muse, mutect2
- AXL | c.2460C>G p.L820= (on ENST00000301178 / NM_021913.5; = p.L811= on NM_001699.6) | Silent (SNP) | VAF 13/256 reads (5%) | called by muse, mutect2
- C19orf73 | c.327C>G p.L109= | Silent (SNP) | VAF 8/142 reads (6%) | called by muse, mutect2
- C2CD2L | c.54C>G p.L18= | Silent (SNP) | VAF 18/384 reads (5%) | called by muse, mutect2
- CACNA1A | c.2211G>T p.A737= | Silent (SNP) | VAF 26/322 reads (8%) | called by muse, mutect2
- CCDC71 | c.252G>A p.T84= | Silent (SNP) | VAF 21/437 reads (5%) | catalogued as rs1297452249; called by muse, mutect2
- CD200 | c.450C>T p.T150= (on ENST00000473539 / NM_001004196.3; = p.T125= on NM_005944.7 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 19/192 reads (10%) | catalogued as COSV59864504; called by muse, mutect2
- CDH22 | c.2469C>T p.D823= | Silent (SNP) | VAF 37/357 reads (10%) | catalogued as rs1241296718; called by muse, mutect2, varscan2
- CDH26 | c.174C>T p.I58= | Silent (SNP) | VAF 21/200 reads (11%) | catalogued as COSV54856596; called by muse, mutect2
- CELF1 | c.438G>C p.L146= | Silent (SNP) | VAF 24/369 reads (7%) | called by muse, mutect2
- CEP170 | c.4662A>G p.E1554= | Silent (SNP) | VAF 22/243 reads (9%) | called by muse, mutect2, varscan2
- CFAP57 | c.783C>G p.V261= | Silent (SNP) | VAF 18/476 reads (4%) | called by muse, mutect2
- COL18A1 | c.3237C>T p.F1079= (on ENST00000359759 / NM_130444.3; = p.F844= on NM_030582.4) | Silent (SNP) | VAF 32/378 reads (8%) | catalogued as rs777848682, COSV60592142; called by muse, mutect2
- COL1A1 | c.912T>A p.R304= | Silent (SNP) | VAF 62/523 reads (12%) | called by muse, mutect2, varscan2
- COL4A1 | c.3714C>T p.R1238= | Silent (SNP) | VAF 53/384 reads (14%) | catalogued as rs377765047; ClinVar: likely benign; called by muse, mutect2, varscan2
- COL6A3 | c.6723G>C p.L2241= | Silent (SNP) | VAF 47/442 reads (11%) | called by muse, mutect2, varscan2
- COL8A1 | c.1566C>T p.G522= | Silent (SNP) | VAF 7/78 reads (9%) | called by muse, mutect2
- CRYBG1 | c.3486G>C p.G1162= | Silent (SNP) | VAF 59/364 reads (16%) | called by muse, mutect2, varscan2
- CTNND2 | c.2610G>T p.L870= | Silent (SNP) | VAF 11/168 reads (7%) | called by muse, mutect2
- DAXX | c.705C>G p.L235= | Silent (SNP) | VAF 14/281 reads (5%) | called by muse, mutect2
- DHRS7C | c.588G>A p.K196= (on ENST00000330255 / NM_001220493.2; = p.K195= on NM_001105571.3) | Silent (SNP) | VAF 16/169 reads (9%) | called by muse, mutect2
- DNAH10 | c.7945C>T p.L2649= (on ENST00000409039; = p.L2588= on NM_207437.3) | Silent (SNP) | VAF 63/535 reads (12%) | called by muse, mutect2, varscan2
- DNAH9 | c.5421G>T p.L1807= | Silent (SNP) | VAF 23/158 reads (15%) | called by muse, mutect2, varscan2
- DNAH9 | c.8859C>T p.L2953= | Silent (SNP) | VAF 11/138 reads (8%) | called by muse, mutect2
- DNHD1 | c.9165G>T p.V3055= | Silent (SNP) | VAF 40/399 reads (10%) | called by muse, mutect2, varscan2
- DPF2 | c.543A>T p.G181= | Silent (SNP) | VAF 13/172 reads (8%) | called by muse, mutect2
- DTX2 | c.501C>T p.S167= | Silent (SNP) | VAF 22/574 reads (4%) | catalogued as COSV56858905; called by muse, mutect2
- EFCAB12 | c.1473G>A p.V491= | Silent (SNP) | VAF 8/129 reads (6%) | called by muse, mutect2
- EIF2B4 | c.759G>C p.V253= (on ENST00000347454 / NM_001034116.2; = p.V252= on NM_015636.3) | Silent (SNP) | VAF 24/611 reads (4%) | called by muse, mutect2
- EIF2S3B | c.171C>A p.V57= | Silent (SNP) | VAF 36/493 reads (7%) | called by muse, mutect2
- ENOX2 | c.1728C>G p.L576= (on ENST00000338144 / NM_001382520.1; = p.L547= on NM_006375.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 14/137 reads (10%) | catalogued as rs369722774; called by muse, mutect2, varscan2
- EPG5 | c.5538G>A p.L1846= | Silent (SNP) | VAF 10/120 reads (8%) | called by muse, mutect2
- EPHX1 | c.612C>T p.T204= | Silent (SNP) | VAF 20/176 reads (11%) | catalogued as rs767567902; called by muse, mutect2, varscan2
- EXOC6B | c.1935C>G p.L645= | Silent (SNP) | VAF 25/330 reads (8%) | called by muse, mutect2
- FAAH | c.1089C>T p.F363= | Silent (SNP) | VAF 40/708 reads (6%) | catalogued as rs759383262; called by muse, mutect2
- FAM135B | c.1953C>T p.P651= | Silent (SNP) | VAF 13/198 reads (7%) | called by muse, mutect2
- FAM53C | c.639C>T p.G213= | Silent (SNP) | VAF 35/661 reads (5%) | called by muse, mutect2
- FCER2 | c.853C>T p.L285= | Silent (SNP) | VAF 34/454 reads (7%) | called by muse, mutect2
- FFAR2 | c.306C>T p.G102= | Silent (SNP) | VAF 56/304 reads (18%) | called by muse, varscan2
- FMN2 | c.2298T>C p.R766= | Silent (SNP) | VAF 33/345 reads (10%) | called by muse, mutect2
- FSCN2 | c.1179C>G p.V393= | Silent (SNP) | VAF 20/304 reads (7%) | called by muse, mutect2
- GCN1 | c.1530G>C p.L510= | Silent (SNP) | VAF 19/276 reads (7%) | catalogued as COSV56115230; called by muse, mutect2
- GLI4 | c.672G>T p.S224= | Silent (SNP) | VAF 22/455 reads (5%) | called by muse, mutect2
- GRIP1 | c.117G>A p.V39= | Silent (SNP) | VAF 27/571 reads (5%) | called by muse, mutect2
- H1-7 | c.423G>A p.T141= | Silent (SNP) | VAF 32/592 reads (5%) | called by muse, mutect2
- HERC1 | c.2391A>G p.L797= | Silent (SNP) | VAF 35/248 reads (14%) | called by muse, mutect2, varscan2
- HIVEP2 | c.4113G>A p.E1371= | Silent (SNP) | VAF 18/258 reads (7%) | called by muse, mutect2
- HMCN1 | c.2260T>C p.L754= | Silent (SNP) | VAF 24/514 reads (5%) | called by muse, mutect2
- HUWE1 | c.4908C>T p.S1636= | Silent (SNP) | VAF 14/188 reads (7%) | catalogued as rs1398662953, COSV99471471; called by muse, mutect2
- IBA57 | c.75G>T p.A25= | Silent (SNP) | VAF 12/89 reads (13%) | called by muse, mutect2, varscan2
- ICA1L | c.1206C>G p.L402= | Silent (SNP) | VAF 17/443 reads (4%) | catalogued as COSV64172688; called by muse, mutect2
- IFFO1 | c.129C>G p.L43= | Silent (SNP) | VAF 12/301 reads (4%) | called by muse, mutect2
- IGSF11 | c.1086C>A p.T362= (on ENST00000393775 / NM_001015887.3; = p.T361= on NM_152538.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/351 reads (4%) | catalogued as COSV61176845; called by muse, mutect2
- INTS1 | c.6543G>C p.L2181= | Silent (SNP) | VAF 9/171 reads (5%) | called by muse, mutect2
- IVNS1ABP | c.1800G>C p.G600= | Silent (SNP) | VAF 25/440 reads (6%) | catalogued as COSV62250624; called by muse, mutect2
- KCNH6 | c.2058G>A p.Q686= | Silent (SNP) | VAF 22/464 reads (5%) | called by muse, mutect2
- KDM5A | c.4143C>T p.I1381= | Silent (SNP) | VAF 16/408 reads (4%) | catalogued as COSV66995974; called by muse, mutect2
- KDM6B | c.3453G>T p.V1151= | Silent (SNP) | VAF 33/604 reads (5%) | called by muse, mutect2
- KIAA1841 | c.1881G>A p.K627= | Silent (SNP) | VAF 18/304 reads (6%) | called by muse, mutect2
- KIZ | c.364C>T p.L122= | Silent (SNP) | VAF 9/125 reads (7%) | catalogued as rs1380299495; called by muse, mutect2
- KLHDC8A | c.240G>T p.R80= | Silent (SNP) | VAF 10/176 reads (6%) | called by muse, mutect2
- KPNA2 | c.1032C>T p.L344= | Silent (SNP) | VAF 18/470 reads (4%) | called by muse, mutect2
- LIMCH1 | c.1815G>C p.L605= | Silent (SNP) | VAF 13/337 reads (4%) | called by muse, mutect2
- LIMD1 | c.1695C>T p.I565= | Silent (SNP) | VAF 18/351 reads (5%) | called by muse, mutect2
- LPA | c.3345C>T p.Y1115= | Silent (SNP) | VAF 33/481 reads (7%) | catalogued as rs924512850; called by muse, mutect2
- LRP2 | c.51C>G p.V17= | Silent (SNP) | VAF 32/474 reads (7%) | called by muse, mutect2
- LRRC14 | c.1230C>G p.L410= | Silent (SNP) | VAF 16/342 reads (5%) | called by muse, mutect2
- LRRC14B | c.1236C>G p.L412= | Silent (SNP) | VAF 20/395 reads (5%) | called by muse, mutect2
- LRRC24 | c.990C>A p.L330= | Silent (SNP) | VAF 10/191 reads (5%) | called by muse, mutect2
- LTB | c.114C>T p.I38= | Silent (SNP) | VAF 13/276 reads (5%) | called by muse, mutect2
- MAGI3 | c.1239G>C p.L413= | Silent (SNP) | VAF 12/220 reads (5%) | called by muse, mutect2
- MAP3K19 | c.774C>G p.L258= | Silent (SNP) | VAF 10/146 reads (7%) | called by muse, mutect2
- MAP6 | c.285G>A p.P95= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as rs527889112; called by muse, mutect2, varscan2
- MCF2L2 | c.2397A>T p.S799= | Silent (SNP) | VAF 8/113 reads (7%) | called by muse, mutect2
- MDN1 | c.12906G>A p.E4302= | Silent (SNP) | VAF 44/415 reads (11%) | catalogued as rs199799891; called by muse, mutect2, varscan2
- MDN1 | c.10842C>G p.L3614= | Silent (SNP) | VAF 24/501 reads (5%) | called by muse, mutect2
- MNS1 | c.132G>A p.Q44= | Silent (SNP) | VAF 19/251 reads (8%) | called by muse, mutect2
- MOCS3 | c.562C>T p.L188= | Silent (SNP) | VAF 13/300 reads (4%) | called by muse, mutect2
- MRC1 | c.1899C>A p.T633= | Silent (SNP) | VAF 23/581 reads (4%) | called by muse, mutect2
- MUC6 | c.2016C>T p.Y672= | Silent (SNP) | VAF 23/433 reads (5%) | catalogued as rs1451474574; called by muse, mutect2
- MYBPC1 | c.573T>C p.S191= (on ENST00000550270 / NM_206820.2; = p.S216= on NM_002465.4) | Silent (SNP) | VAF 28/460 reads (6%) | catalogued as rs1442048569; called by muse, mutect2
- MYH13 | c.3405G>A p.K1135= | Silent (SNP) | VAF 27/286 reads (9%) | called by muse, mutect2
- MYO7A | c.1683G>A p.E561= | Silent (SNP) | VAF 22/259 reads (8%) | called by muse, mutect2
- MYRFL | c.435C>T p.Y145= | Silent (SNP) | VAF 12/180 reads (7%) | called by muse, mutect2
- NCKAP1L | c.1227C>T p.F409= | Silent (SNP) | VAF 9/168 reads (5%) | called by muse, mutect2
- NDST1 | c.426C>G p.L142= | Silent (SNP) | VAF 14/350 reads (4%) | called by muse, mutect2
- NEUROD6 | c.756C>G p.A252= | Silent (SNP) | VAF 16/361 reads (4%) | called by muse, mutect2
- NKX3-2 | c.564G>T p.G188= | Silent (SNP) | VAF 25/207 reads (12%) | called by muse, mutect2, varscan2
- NLGN4X | c.1548C>T p.D516= | Silent (SNP) | VAF 31/361 reads (9%) | catalogued as rs769290806, COSV52011907; called by muse, mutect2
- NLRP2 | c.1009C>A p.R337= | Silent (SNP) | VAF 13/228 reads (6%) | called by muse, mutect2
- NLRP9 | c.1047G>A p.Q349= | Silent (SNP) | VAF 15/396 reads (4%) | catalogued as COSV60460519; called by muse, mutect2
- NOC3L | c.1107C>G p.L369= | Silent (SNP) | VAF 8/142 reads (6%) | called by muse, mutect2
- NPIPA5 | c.441G>C p.L147= | Silent (SNP) | VAF 14/620 reads (2%) | called by muse, mutect2
- NSMAF | c.1383G>C p.L461= | Silent (SNP) | VAF 14/266 reads (5%) | catalogued as COSV50700251; called by muse, mutect2
- NT5E | c.1293G>A p.L431= | Silent (SNP) | VAF 36/732 reads (5%) | called by muse, mutect2
- OAZ1 | c.594G>C p.V198= | Silent (SNP) | VAF 19/405 reads (5%) | called by muse, mutect2
- OR4N2 | c.201C>T p.A67= | Silent (SNP) | VAF 15/204 reads (7%) | called by muse, mutect2
- OR4P4 | c.192C>A p.L64= | Silent (SNP) | VAF 10/48 reads (21%) | called by muse, mutect2, varscan2
- OR5P3 | c.666C>T p.L222= | Silent (SNP) | VAF 21/282 reads (7%) | catalogued as COSV60430249; called by muse, mutect2
- OR6Y1 | c.363T>C p.A121= | Silent (SNP) | VAF 31/370 reads (8%) | catalogued as COSV56928105; called by muse, mutect2
- ORC4 | c.1296A>C p.S432= | Silent (SNP) | VAF 20/272 reads (7%) | catalogued as rs1194503983; called by muse, mutect2
- ORC5 | c.141A>G p.T47= | Silent (SNP) | VAF 10/86 reads (12%) | called by muse, mutect2, varscan2
- OTOG | c.345C>T p.F115= | Silent (SNP) | VAF 11/270 reads (4%) | called by muse, mutect2
- PARP1 | c.2634G>C p.R878= | Silent (SNP) | VAF 29/398 reads (7%) | called by muse, mutect2
- PAX7 | c.165C>T p.I55= | Silent (SNP) | VAF 22/522 reads (4%) | catalogued as rs1282632111; called by muse, mutect2
- PCDHA11 | c.1683G>C p.A561= | Silent (SNP) | VAF 36/774 reads (5%) | catalogued as COSV56537339; called by muse, mutect2
- PCDHB1 | c.1302C>T p.A434= | Silent (SNP) | VAF 21/274 reads (8%) | catalogued as rs781869991, COSV60633652; called by muse, mutect2
- PGA5 | c.855C>A p.G285= | Silent (SNP) | VAF 60/679 reads (9%) | called by muse, mutect2
- PHYHIP | c.564G>A p.T188= | Silent (SNP) | VAF 14/148 reads (9%) | catalogued as rs974105334; called by muse, mutect2
- PIK3C3 | c.2625G>T p.V875= | Silent (SNP) | VAF 16/208 reads (8%) | catalogued as COSV56285805; called by muse, mutect2
- PIP4K2C | c.870C>T p.I290= | Silent (SNP) | VAF 29/401 reads (7%) | called by muse, mutect2
- PKDREJ | c.4059T>A p.T1353= | Silent (SNP) | VAF 17/186 reads (9%) | called by muse, mutect2
- PLEC | c.6795G>T p.R2265= (on ENST00000322810 / NM_201380.4; = p.R2155= on NM_000445.5) | Silent (SNP) | VAF 18/426 reads (4%) | called by muse, mutect2
- PLEKHG6 | c.657C>T p.H219= | Silent (SNP) | VAF 24/228 reads (11%) | called by muse, mutect2
- PRDM13 | c.696T>C p.S232= | Silent (SNP) | VAF 18/274 reads (7%) | called by muse, mutect2
- PREX1 | c.2010C>A p.S670= | Silent (SNP) | VAF 12/285 reads (4%) | called by muse, mutect2
- PRRC2B | c.1596G>A p.L532= | Silent (SNP) | VAF 21/305 reads (7%) | called by muse, mutect2
- PYCR3 | c.216C>T p.V72= | Silent (SNP) | VAF 14/192 reads (7%) | called by muse, mutect2
- RAB11FIP1 | c.3597C>T p.I1199= (on ENST00000330843 / NM_001002814.3; = p.I565= on NM_025151.5) | Silent (SNP) | VAF 9/168 reads (5%) | called by muse, mutect2
- RBAK | c.885G>T p.G295= | Silent (SNP) | VAF 12/204 reads (6%) | called by muse, mutect2
- RC3H2 | c.3039G>A p.Q1013= | Silent (SNP) | VAF 20/275 reads (7%) | called by muse, mutect2
- RGSL1 | c.1893C>G p.L631= | Silent (SNP) | VAF 22/347 reads (6%) | called by muse, mutect2
- RHPN1 | c.387G>C p.L129= | Silent (SNP) | VAF 14/298 reads (5%) | called by muse, mutect2
- RNF19A | c.2034G>A p.L678= | Silent (SNP) | VAF 13/312 reads (4%) | called by muse, mutect2
- RTEL1 | c.3237C>G p.L1079= | Silent (SNP) | VAF 24/373 reads (6%) | called by muse, mutect2
- RUSF1 | c.903G>A p.Q301= | Silent (SNP) | VAF 29/593 reads (5%) | catalogued as COSV100393047; called by muse, mutect2
- SBSN | c.1413G>A p.K471= (on ENST00000452271 / NM_001166034.2; = p.K128= on NM_198538.4) | Silent (SNP) | VAF 22/418 reads (5%) | called by muse, mutect2
155 further variants in this file (0 protein-altering or splice-affecting, 47 silent, 108 other) are not listed here.
